Somatic mutation profile of cancer-model specimen HCM-BROD-0227-C43-85M (Adherent Cell Line, passage 11; aliquot HCM-BROD-0227-C43-85M-01D-A78T-36), derived from the metastatic tumor of HCMI case HCM-BROD-0227-C43, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 40.5 years (14,805 days).
Specimen HCM-BROD-0227-C43-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 11.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f0d13d9e-fa66-46d3-931d-5f39fb040e93.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0227-C43-10A (Blood Derived Normal), aliquot HCM-BROD-0227-C43-10A-01D-A78T-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/db82aa2d-ec19-46c0-ab5a-f8d2801cc25c

The open-access MAF lists 4,189 somatic variants for this specimen: 2,452 protein-altering or splice-affecting, 1,215 silent, 522 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2,238, Silent 1,215, Intron 263, Nonsense Mutation 127, RNA 90, 3'UTR 79, 5'UTR 44, Splice Region 42, Splice Site 31, 5'Flank 30, 3'Flank 14, Translation Start Site 5.

Variants (750 of 4,189; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCB4 | c.139C>T p.R47* | Nonsense Mutation (SNP) | VAF 16/52 reads (31%) | catalogued as rs376926391, CM082466, CM122251; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ASNS | c.1439C>T p.S480F | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs754043007, CM163694, COSV99446791; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- CARD14 | c.349G>A p.G117S | Missense Mutation (SNP) | VAF 130/260 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs281875215, CM1213173, CS123490, COSV100712560, COSV60124009; ClinVar: pathogenic / not provided; called by muse, mutect2, varscan2
- CDKN2A | c.238C>T p.R80* | Nonsense Mutation (SNP) | VAF 470/536 reads (88%) | hotspot (GDC flag); catalogued as rs121913388, CM014695, COSV58682746, COSV58721651; ClinVar: risk factor / likely pathogenic; called by muse, mutect2, varscan2
- COL3A1 | c.593G>A p.G198E | Missense Mutation (SNP) | VAF 52/117 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs587779641, CM1412413; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- COL4A5 | c.2537G>A p.G846E | Missense Mutation (SNP) | VAF 116/121 reads (96%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1569497690; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- GUSB | c.1429C>T p.R477W | Missense Mutation (SNP) | VAF 109/289 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs774393243, CM960803, COSV104396132; ClinVar: pathogenic; called by muse, varscan2
- RB1 | c.1696-1G>A p.X566_splice | Splice Site (SNP) | VAF 31/40 reads (78%) | catalogued as rs794727199, CS951523, COSV57329272; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.949C>T p.Q317* | Nonsense Mutation (SNP) | VAF 196/210 reads (93%) | hotspot (GDC flag); catalogued as rs764735889, COSV52685086, COSV53209009; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AADAC | c.750G>A p.W250* | Nonsense Mutation (SNP) | VAF 11/62 reads (18%) | catalogued as COSV51758616; called by muse, mutect2, varscan2
- AARS2 | c.1051C>T p.R351C | Missense Mutation (SNP) | VAF 357/800 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs766485554, COSV55116456; called by muse, mutect2, varscan2
- ABCA12 | c.2509G>A p.E837K (on ENST00000272895 / NM_173076.3; = p.E519K on NM_015657.3) | Missense Mutation (SNP) | VAF 72/112 reads (64%) | SIFT tolerated (0.91); PolyPhen benign (0.031); catalogued as COSV55966716; called by muse, varscan2
- ABCA12 | c.1192C>T p.L398F (on ENST00000272895 / NM_173076.3; = p.L80F on NM_015657.3) | Missense Mutation (SNP) | VAF 12/77 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs1310268099; called by muse, mutect2, varscan2
- ABCA8 | c.3218C>T p.S1073F | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.673); catalogued as rs759445548; called by muse, mutect2, varscan2
- ABCB9 | c.986C>T p.S329F | Missense Mutation (SNP) | VAF 95/177 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs770574958, COSV54893148; called by muse, mutect2, varscan2
- ABCC11 | c.1445C>T p.S482L | Missense Mutation (SNP) | VAF 384/414 reads (93%) | SIFT deleterious (0); PolyPhen benign (0.117); catalogued as COSV62322687; called by muse, mutect2, varscan2
- ABCC4 | c.3932C>T p.S1311F | Missense Mutation (SNP) | VAF 55/65 reads (85%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.361); catalogued as COSV65313632; called by muse, mutect2, varscan2
- ABCF2 | c.1543C>T p.R515W | Missense Mutation (SNP) | VAF 72/192 reads (38%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.952); catalogued as rs762920767; called by muse, mutect2, varscan2
- ABCF3 | c.2090C>T p.A697V | Missense Mutation (SNP) | VAF 96/232 reads (41%) | SIFT deleterious (0.02); PolyPhen benign (0.067); catalogued as rs191518353; called by muse, mutect2, varscan2
- ABI3BP | c.1357C>T p.P453S | Missense Mutation (SNP) | VAF 115/256 reads (45%) | SIFT tolerated (0.19); PolyPhen benign (0.005); catalogued as COSV52536556; called by muse, mutect2, varscan2
- ACAA2 | c.973C>T p.P325S | Missense Mutation (SNP) | VAF 17/110 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.062); catalogued as rs763895191, COSV53270277; called by muse, mutect2, varscan2
- ACACA | c.3272C>T p.T1091I | Missense Mutation (SNP) | VAF 136/327 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.36); catalogued as rs1429729354; called by muse, mutect2, varscan2
- ACAD10 | c.1628C>T p.P543L | Missense Mutation (SNP) | VAF 52/192 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs767526611, COSV58161515; called by muse, mutect2, varscan2
- ACOT12 | c.627G>A p.M209I | Missense Mutation (SNP) | VAF 24/82 reads (29%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.954); catalogued as COSV56893224; called by muse, mutect2
- ACOXL | c.857G>A p.R286Q | Missense Mutation (SNP) | VAF 68/175 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.812); catalogued as rs1203462539, COSV67735979; called by muse, mutect2, varscan2
- ACSM2B | c.420G>A p.M140I | Missense Mutation (SNP) | VAF 86/105 reads (82%) | SIFT deleterious (0); PolyPhen benign (0.145); catalogued as COSV61656609; called by muse, mutect2, varscan2
- ACSM5 | c.706G>A p.A236T | Missense Mutation (SNP) | VAF 85/95 reads (89%) | SIFT tolerated (0.39); PolyPhen benign (0.014); catalogued as rs748617727, COSV100089269; called by muse, mutect2, varscan2
- ACSM5 | c.1243G>A p.E415K | Missense Mutation (SNP) | VAF 230/267 reads (86%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1218512715; called by muse, mutect2, varscan2
- ACSS3 | c.628C>T p.R210C | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs760939820, COSV54098981; called by muse, mutect2
- ACSS3 | c.790C>T p.P264S | Missense Mutation (SNP) | VAF 25/45 reads (56%) | SIFT tolerated (0.49); PolyPhen benign (0.039); catalogued as COSV54102782; called by muse, mutect2, varscan2
- ACSS3 | c.1433G>A p.S478N | Missense Mutation (SNP) | VAF 61/111 reads (55%) | SIFT deleterious (0); PolyPhen benign (0.209); catalogued as rs781051176; called by muse, mutect2, varscan2
- ACTR3C | c.107C>T p.P36L | Missense Mutation (SNP) | VAF 96/218 reads (44%) | SIFT deleterious, low confidence (0); catalogued as rs1270657771; called by muse, mutect2, varscan2
- ACTRT3 | c.721G>A p.D241N | Missense Mutation (SNP) | VAF 35/74 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.85); catalogued as COSV57754538; called by muse, mutect2, varscan2
- ADAM18 | c.429G>A p.M143I | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV55850127; called by muse, mutect2, varscan2
- ADAM20 | c.740C>T p.P247L | Missense Mutation (SNP) | VAF 36/80 reads (45%) | SIFT tolerated (0.21); PolyPhen benign (0.111); catalogued as COSV56456519, COSV99833610; called by muse, varscan2
- ADAM29 | c.902G>A p.G301E | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.762); catalogued as rs376197978; called by muse, mutect2, varscan2
- ADAM29 | c.1687C>T p.P563S | Missense Mutation (SNP) | VAF 38/61 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV63665732; called by muse, mutect2, varscan2
- ADAMDEC1 | c.383G>A p.G128E | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs976542769, COSV99835917; called by muse, mutect2, varscan2
- ADAMTS14 | c.1372G>A p.D458N | Missense Mutation (SNP) | VAF 38/97 reads (39%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.95); catalogued as rs373853037, COSV100941843; called by muse, mutect2, varscan2
- ADAMTS18 | c.2258G>A p.G753D | Missense Mutation (SNP) | VAF 147/169 reads (87%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as rs1338155250, COSV51402204; called by muse, mutect2, varscan2
- ADD2 | c.852C>T p.I284= | Splice Region (SNP) | VAF 88/151 reads (58%) | catalogued as rs1011668406; called by muse, mutect2, varscan2
- ADGRB3 | c.3499G>A p.D1167N | Missense Mutation (SNP) | VAF 45/92 reads (49%) | SIFT tolerated (0.07); PolyPhen benign (0.057); catalogued as rs1412577858; called by muse, mutect2, varscan2
- ADGRE1 | c.1533G>A p.M511I | Missense Mutation (SNP) | VAF 267/352 reads (76%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as COSV51676838; called by muse, mutect2, varscan2
- ADGRF1 | c.988C>T p.L330F | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99347347; called by muse, mutect2, varscan2
- ADGRF3 | c.830C>T p.P277L | Missense Mutation (SNP) | VAF 209/342 reads (61%) | SIFT tolerated (0.44); PolyPhen benign (0.005); catalogued as rs1393284176; called by muse, mutect2, varscan2
- ADGRG4 | c.1474C>T p.P492S | Missense Mutation (SNP) | VAF 50/52 reads (96%) | SIFT deleterious (0.05); PolyPhen benign (0.015); catalogued as rs779874865, COSV54950665; called by muse, mutect2, varscan2
- ADGRV1 | c.3925C>T p.P1309S | Missense Mutation (SNP) | VAF 66/224 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.106); catalogued as COSV67978443; called by muse, mutect2, varscan2
- ADGRV1 | c.6082C>T p.P2028S | Missense Mutation (SNP) | VAF 94/165 reads (57%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.685); catalogued as COSV101316015; called by muse, mutect2, varscan2
- ADGRV1 | c.9094C>T p.L3032F | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.65); PolyPhen benign (0.011); catalogued as COSV67978992, COSV67980365; called by muse, mutect2
- ADH6 | c.106G>A p.E36K | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1358708729, COSV52955815; called by muse, mutect2, varscan2
- ADRA1B | c.571G>A p.D191N | Missense Mutation (SNP) | VAF 69/209 reads (33%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.899); catalogued as rs762712089, COSV60703629; called by muse, mutect2, varscan2
- AFF3 | c.3317C>T p.P1106L | Missense Mutation (SNP) | VAF 52/216 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); catalogued as rs569849120; called by muse, mutect2, varscan2
- AGO4 | c.854C>T p.P285L | Missense Mutation (SNP) | VAF 23/94 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.034); catalogued as COSV64618801; called by muse, mutect2, varscan2
- AHNAK2 | c.14855C>T p.P4952L | Missense Mutation (SNP) | VAF 54/227 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.173); catalogued as rs1160915339; called by muse, mutect2, varscan2
- AJUBA | c.662G>A p.G221E | Missense Mutation (SNP) | VAF 51/115 reads (44%) | SIFT tolerated (0.22); PolyPhen benign (0.243); catalogued as rs936568030; called by muse, mutect2, varscan2
- AKAP3 | c.82C>T p.Q28* | Nonsense Mutation (SNP) | VAF 69/105 reads (66%) | catalogued as COSV57414126; called by muse, mutect2, varscan2
- AKR1D1 | c.224G>A p.G75E | Missense Mutation (SNP) | VAF 73/162 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); catalogued as rs146708783, COSV54341545; called by muse, mutect2, varscan2
- ALAS1 | c.842G>A p.R281K | Missense Mutation (SNP) | VAF 22/139 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.968); catalogued as COSV59627415; called by muse, mutect2, varscan2
- ALB | c.23C>T p.S8F | Missense Mutation (SNP) | VAF 42/162 reads (26%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.59); catalogued as rs1445148767, COSV55738215; called by muse, mutect2, varscan2
- ALDH2 | c.251G>C p.R84P | Missense Mutation (SNP) | VAF 172/276 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV55671934; called by muse, varscan2
- ALDOB | c.137G>A p.R46K | Missense Mutation (SNP) | VAF 75/188 reads (40%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs199920124, COSV66398746; called by muse, mutect2, varscan2
- ALG9 | c.1330C>T p.P444S (on ENST00000614444 / NM_001352418.1; = p.P451S on NM_024740.2) | Missense Mutation (SNP) | VAF 94/225 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.082); catalogued as rs782727331; called by muse, mutect2, varscan2
- ALK | c.4045G>A p.D1349N | Missense Mutation (SNP) | VAF 54/204 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.91); catalogued as COSV66557974, COSV66589553; called by muse, varscan2
- ALPI | c.688G>A p.G230R | Missense Mutation (SNP) | VAF 67/105 reads (64%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.98); catalogued as rs1416599063; called by muse, mutect2, varscan2
- ALPK1 | c.2152C>T p.R718C | Missense Mutation (SNP) | VAF 68/110 reads (62%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs771984525, COSV51582524; called by muse, mutect2, varscan2
- ALPK3 | c.3176G>A p.R1059Q | Missense Mutation (SNP) | VAF 158/336 reads (47%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs1240729658; called by muse, mutect2, varscan2
- AMER3 | c.1000G>A p.G334R | Missense Mutation (SNP) | VAF 167/264 reads (63%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.813); catalogued as COSV100366741; called by muse, mutect2, varscan2
- AMER3 | c.1598C>T p.S533F | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs770680817; called by muse, mutect2, varscan2
- AMHR2 | c.142G>A p.E48K | Missense Mutation (SNP) | VAF 208/346 reads (60%) | SIFT tolerated (0.09); PolyPhen benign (0.053); catalogued as COSV57685390, COSV99142993; called by muse, mutect2, varscan2
- ANGPT4 | c.358C>T p.Q120* | Nonsense Mutation (SNP) | VAF 119/287 reads (41%) | catalogued as COSV67922954; called by muse, mutect2, varscan2
- ANK1 | c.2890C>T p.P964S | Missense Mutation (SNP) | VAF 130/401 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as rs1427523626; called by muse, mutect2, varscan2
- ANK2 | c.220G>A p.E74K | Missense Mutation (SNP) | VAF 168/284 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52152825; called by muse, mutect2, varscan2
- ANK3 | c.9152C>T p.S3051F | Missense Mutation (SNP) | VAF 8/13 reads (62%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs563874031, COSV55079709; called by muse, mutect2, varscan2
- ANKEF1 | c.605G>A p.R202Q | Missense Mutation (SNP) | VAF 58/164 reads (35%) | SIFT tolerated (0.06); PolyPhen benign (0.095); catalogued as rs983971911; called by muse, mutect2, varscan2
- ANKRD30A | c.3552A>T p.E1184D (on ENST00000611781; = p.E1128D on NM_052997.2) | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.757); catalogued as rs1387380477; called by muse, mutect2, varscan2
- ANKRD36 | c.2665A>C p.K889Q | Missense Mutation (SNP) | VAF 66/194 reads (34%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.279); catalogued as rs1351231145, COSV70738214; called by muse, mutect2, varscan2
- ANKRD62 | c.2128G>A p.E710K | Missense Mutation (SNP) | VAF 31/50 reads (62%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.986); catalogued as rs1175807785; called by muse, mutect2, varscan2
- ANO2 | c.838G>A p.E280K (on ENST00000356134 / NM_001278597.3; = p.E284K on NM_001278596.3) | Missense Mutation (SNP) | VAF 48/223 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.732); catalogued as rs1485146496, COSV59031608; called by muse, mutect2, varscan2
- ANO7 | c.992C>T p.P331L (on ENST00000274979; = p.P277L on NM_001370694.2) | Missense Mutation (SNP) | VAF 61/201 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51478389; called by muse, varscan2
- AOPEP | c.1849C>T p.H617Y (on ENST00000375315 / NM_001193329.1; = p.H518Y on NM_032823.5) | Missense Mutation (SNP) | VAF 35/48 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV52994789; called by muse, mutect2, varscan2
- AOX1 | c.1066G>A p.G356R | Missense Mutation (SNP) | VAF 47/90 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs1398696052; called by muse, mutect2, varscan2
- AP3B1 | c.1828C>T p.P610S | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.95); PolyPhen benign (0.014); catalogued as rs1227861460; called by muse, mutect2, varscan2
- APBB1IP | c.602G>A p.R201Q | Missense Mutation (SNP) | VAF 46/136 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.012); catalogued as rs779560771, COSV63076096, COSV63076563; called by muse, mutect2, varscan2
- APCDD1 | c.412C>T p.R138* | Nonsense Mutation (SNP) | VAF 48/158 reads (30%) | catalogued as rs373747410; called by muse, mutect2, varscan2
- APOB | c.10899G>A p.W3633* | Nonsense Mutation (SNP) | VAF 22/85 reads (26%) | catalogued as COSV51938071; called by muse, mutect2, varscan2
- APOL3 | c.469C>T p.P157S (on ENST00000349314 / NM_145640.2; = p.P86S on NM_014349.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 51/164 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV62580721; called by muse, mutect2, varscan2
- ARHGAP22 | c.1880G>A p.G627E | Missense Mutation (SNP) | VAF 42/101 reads (42%) | SIFT tolerated (0.6); PolyPhen benign (0.154); catalogued as rs1453849902; called by muse, mutect2, varscan2
- ARHGAP22 | c.448G>A p.G150R | Missense Mutation (SNP) | VAF 92/193 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as rs369200749, COSV50932711; called by muse, mutect2, varscan2
- ARHGAP30 | c.2611G>A p.E871K | Missense Mutation (SNP) | VAF 76/291 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.024); catalogued as COSV63518949; called by muse, mutect2, varscan2
- ARHGAP36 | c.437C>T p.A146V | Missense Mutation (SNP) | VAF 415/445 reads (93%) | SIFT tolerated (0.14); PolyPhen benign (0.015); catalogued as COSV99035101; called by muse, mutect2, varscan2
- ARHGEF40 | c.2972C>T p.S991F | Missense Mutation (SNP) | VAF 116/262 reads (44%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.456); catalogued as rs1167118016, COSV53880017; called by muse, mutect2, varscan2
- ARMC9 | c.1519C>T p.L507F | Missense Mutation (SNP) | VAF 67/231 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs763517346, COSV63022284; called by muse, mutect2, varscan2
- ARNT | c.112C>T p.Q38* | Nonsense Mutation (SNP) | VAF 59/201 reads (29%) | catalogued as rs746667101; called by muse, mutect2, varscan2
- ARPP21 | c.898-3C>T | Splice Region (SNP) | VAF 40/99 reads (40%) | catalogued as COSV99491270; called by muse, mutect2, varscan2
- ARRDC5 | c.730C>T p.R244W (on ENST00000381781; = p.R230W on NM_001080523.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 62/137 reads (45%) | SIFT tolerated (0.18); PolyPhen benign (0.133); catalogued as rs548886303, COSV67787986; called by muse, mutect2, varscan2
- ARSG | c.454G>A p.G152S | Missense Mutation (SNP) | VAF 62/353 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101477883; called by muse, mutect2, varscan2
- ASNS | c.1057C>T p.R353W | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.713); catalogued as rs370383154; called by muse, mutect2, varscan2
- ASPG | c.1070G>A p.R357Q | Missense Mutation (SNP) | VAF 204/432 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs766837441, COSV101496412; called by muse, varscan2
- ASPM | c.6301C>T p.Q2101* | Nonsense Mutation (SNP) | VAF 49/92 reads (53%) | catalogued as COSV99661078; called by muse, mutect2, varscan2
- ASTN1 | c.1133G>A p.R378Q | Missense Mutation (SNP) | VAF 50/83 reads (60%) | SIFT tolerated (0.08); PolyPhen benign (0.021); catalogued as rs760442147, COSV56061330; called by muse, mutect2, varscan2
- ATF7IP2 | c.779C>T p.S260L | Missense Mutation (SNP) | VAF 17/19 reads (89%) | SIFT tolerated (0.15); PolyPhen benign (0.009); catalogued as COSV61094801; called by muse, mutect2, varscan2
- ATG2B | c.6106C>T p.P2036S | Missense Mutation (SNP) | VAF 192/450 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1019231132, COSV55890235; called by muse, mutect2, varscan2
- ATP13A5 | c.2942C>T p.S981F | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.022); catalogued as rs747678157; called by muse, varscan2
- ATP13A5 | c.2050G>A p.E684K | Missense Mutation (SNP) | VAF 50/95 reads (53%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.665); catalogued as COSV60865921; called by muse, mutect2, varscan2
- ATP1A3 | c.2404C>T p.P802S (on ENST00000545399 / NM_001256214.2; = p.P789S on NM_152296.5) | Missense Mutation (SNP) | VAF 479/642 reads (75%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100132235; called by muse, mutect2, varscan2
- ATP2B2 | c.2422G>A p.G808R (on ENST00000352432; = p.G774R on NM_001683.5) | Missense Mutation (SNP) | VAF 108/470 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59491379; called by muse, varscan2
- ATP6V0D2 | c.1019G>A p.R340Q | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.521); catalogued as rs781030035, COSV53413746; called by muse, mutect2
- ATP6V1C2 | c.629G>A p.R210Q | Missense Mutation (SNP) | VAF 51/235 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs267598832, COSV55365148; called by muse, mutect2
- ATP8A1 | c.3487G>A p.E1163K | Missense Mutation (SNP) | VAF 36/117 reads (31%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.001); catalogued as rs751157914, COSV52533125, COSV52543860; called by muse, mutect2, varscan2
- ATP8A1 | c.1481G>A p.R494Q | Missense Mutation (SNP) | VAF 72/129 reads (56%) | SIFT tolerated (0.08); PolyPhen benign (0.223); catalogued as rs373156864, COSV52535629; called by muse, varscan2
- ATP9A | c.733G>A p.D245N | Missense Mutation (SNP) | VAF 139/306 reads (45%) | SIFT tolerated (0.12); PolyPhen benign (0.053); catalogued as rs780455528, COSV58763874; called by muse, mutect2, varscan2
- ATRN | c.1004C>T p.S335F | Missense Mutation (SNP) | VAF 42/86 reads (49%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as rs961276222; called by muse, mutect2, varscan2
- AZGP1 | c.337+1G>A p.X113_splice | Splice Site (SNP) | VAF 29/66 reads (44%) | catalogued as rs757263796, COSV52797039; called by muse, mutect2
- AZGP1 | c.179G>A p.R60K | Missense Mutation (SNP) | VAF 57/137 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as COSV52799093; called by muse, mutect2, varscan2
- BCAM | c.134G>A p.R45Q | Missense Mutation (SNP) | VAF 138/1025 reads (13%) | SIFT tolerated (0.35); PolyPhen benign (0.018); catalogued as rs201126501; called by muse, mutect2, varscan2
- BCL9 | c.1549C>T p.P517S | Missense Mutation (SNP) | VAF 37/98 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs782286134; called by muse, mutect2, varscan2
- BGN | c.751C>T p.R251C | Missense Mutation (SNP) | VAF 214/234 reads (91%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.826); catalogued as rs1418964197, COSV59036177; called by muse, mutect2, varscan2
- BIRC3 | c.118C>T p.P40S | Missense Mutation (SNP) | VAF 31/99 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54815323; called by muse, mutect2, varscan2
- BIRC6 | c.7627C>T p.P2543S | Missense Mutation (SNP) | VAF 47/168 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV70198353; called by muse, mutect2, varscan2
- BMP1 | c.1744C>T p.P582S | Missense Mutation (SNP) | VAF 99/362 reads (27%) | SIFT tolerated (0.94); PolyPhen benign (0.003); catalogued as rs566435924; called by muse, mutect2, varscan2
- BMP3 | c.484C>T p.Q162* | Nonsense Mutation (SNP) | VAF 15/54 reads (28%) | catalogued as rs1162201492, COSV51096071; called by muse, varscan2
- BMP3 | c.556G>A p.D186N | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV99261726; called by muse, varscan2
- BMP4 | c.770C>T p.S257L | Missense Mutation (SNP) | VAF 126/277 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs889958974, COSV55416421; called by muse, mutect2, varscan2
- BMP5 | c.937C>T p.R313* | Nonsense Mutation (SNP) | VAF 77/265 reads (29%) | catalogued as rs1396089139, COSV63701194; called by muse, mutect2, varscan2
- BMP5 | c.358C>T p.P120S | Missense Mutation (SNP) | VAF 66/232 reads (28%) | SIFT tolerated (0.09); PolyPhen benign (0.062); catalogued as COSV63703324; called by muse, mutect2, varscan2
- BNC1 | c.661C>T p.P221S | Missense Mutation (SNP) | VAF 62/130 reads (48%) | SIFT tolerated (0.5); PolyPhen benign (0.037); catalogued as rs1433663057; called by muse, mutect2, varscan2
- BNIP5 | c.1105C>T p.P369S | Missense Mutation (SNP) | VAF 144/312 reads (46%) | SIFT tolerated (0.59); PolyPhen benign (0.001); catalogued as COSV71325282, COSV71325450; called by muse, mutect2, varscan2
- BRD4 | c.3682C>T p.R1228C | Missense Mutation (SNP) | VAF 320/478 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV54582278; called by muse, mutect2, varscan2
- BSN | c.6802C>T p.P2268S | Missense Mutation (SNP) | VAF 25/110 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.196); catalogued as COSV56515788; called by muse, mutect2, varscan2
- BSND | c.152G>A p.W51* | Nonsense Mutation (SNP) | VAF 87/93 reads (94%) | catalogued as COSV64870422; called by muse, mutect2, varscan2
- BTBD17 | c.629C>T p.P210L | Missense Mutation (SNP) | VAF 82/396 reads (21%) | SIFT tolerated (0.3); PolyPhen benign (0.034); catalogued as rs749651472; called by muse, mutect2, varscan2
- BTBD8 | c.2591G>A p.G864E (on ENST00000636805 / NM_001376131.1; = p.G351E on NM_015237.4) | Missense Mutation (SNP) | VAF 19/23 reads (83%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV64884707; called by muse, mutect2, varscan2
- C10orf71 | c.503C>T p.P168L | Missense Mutation (SNP) | VAF 74/212 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as rs369285936; called by muse, mutect2, varscan2
- C11orf53 | c.644C>T p.S215L | Missense Mutation (SNP) | VAF 30/89 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.277); catalogued as rs369356034, COSV54721419; called by muse, mutect2, varscan2
- C12orf56 | c.1511G>A p.G504E (on ENST00000543942 / NM_001170633.2; = p.G344E on NM_001099676.3) | Missense Mutation (SNP) | VAF 39/67 reads (58%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs753165036, COSV100399031; called by muse, mutect2, varscan2
- C1RL | c.1433G>A p.W478* | Nonsense Mutation (SNP) | VAF 25/82 reads (30%) | catalogued as rs994376196; called by muse, mutect2, varscan2
- C5AR2 | c.955G>A p.E319K | Missense Mutation (SNP) | VAF 71/157 reads (45%) | SIFT deleterious (0.05); PolyPhen benign (0.184); catalogued as rs529217199, COSV57255680; called by muse, mutect2, varscan2
- C6 | c.1903C>T p.L635F | Missense Mutation (SNP) | VAF 37/153 reads (24%) | SIFT tolerated (0.25); PolyPhen benign (0.298); catalogued as COSV54712066; called by muse, varscan2
- C8orf34 | c.1306G>A p.E436K | Missense Mutation (SNP) | VAF 29/53 reads (55%) | SIFT tolerated (0.43); PolyPhen benign (0.055); catalogued as COSV57398183; called by muse, mutect2, varscan2
- C9orf57 | c.23G>A p.G8E | Missense Mutation (SNP) | VAF 46/49 reads (94%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.042); catalogued as rs1390875458, COSV65462482; called by muse, mutect2, varscan2
- CA5B | c.848C>T p.P283L | Missense Mutation (SNP) | VAF 71/76 reads (93%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); catalogued as COSV59415920; called by muse, mutect2, varscan2
- CACNA1A | c.1441C>T p.R481C | Missense Mutation (SNP) | VAF 28/209 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1189054127, COSV64209953; called by muse, mutect2, varscan2
- CACNA1C | c.574C>T p.R192C | Missense Mutation (SNP) | VAF 29/104 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.745); catalogued as rs756042537; called by muse, mutect2, varscan2
- CACNA1C | c.5812C>T p.R1938W (on ENST00000399634 / NM_001167625.1; = p.R1867W on NM_000719.7) | Missense Mutation (SNP) | VAF 70/169 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.73); catalogued as rs369421219; ClinVar: uncertain significance; called by muse, varscan2
- CACNA1F | c.5645G>A p.G1882E | Missense Mutation (SNP) | VAF 201/216 reads (93%) | SIFT tolerated, low confidence (0.2); PolyPhen possibly damaging (0.454); catalogued as COSV59904513; called by muse, mutect2, varscan2
- CACNA1I | c.5384C>T p.S1795L | Missense Mutation (SNP) | VAF 37/57 reads (65%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.806); catalogued as rs1026466143; called by muse, mutect2, varscan2
- CACNA1S | c.1801C>T p.P601S | Missense Mutation (SNP) | VAF 119/405 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV62944680; called by muse, mutect2, varscan2
- CACNA2D4 | c.489C>T p.F163= | Splice Region (SNP) | VAF 32/63 reads (51%) | catalogued as COSV54946451; called by muse, mutect2, varscan2
- CACNG4 | c.809C>T p.P270L | Missense Mutation (SNP) | VAF 105/410 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.573); catalogued as COSV50924770; called by muse, mutect2, varscan2
- CADM1 | c.1018C>T p.P340S | Missense Mutation (SNP) | VAF 32/74 reads (43%) | SIFT tolerated (0.37); PolyPhen benign (0.012); catalogued as COSV59014471; called by muse, varscan2
- CADM2 | c.1061G>A p.R354K (on ENST00000407528 / NM_001167674.2; = p.R356K on NM_153184.4) | Missense Mutation (SNP) | VAF 52/104 reads (50%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as COSV67390007; called by muse, varscan2
- CADPS | c.3463G>A p.E1155K | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.108); catalogued as rs368477906; called by muse, mutect2
- CADPS | c.2822C>T p.P941L | Missense Mutation (SNP) | VAF 56/155 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs765183785; called by muse, mutect2, varscan2
- CADPS | c.2593G>A p.D865N | Missense Mutation (SNP) | VAF 20/38 reads (53%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.992); catalogued as COSV51876366; called by muse, mutect2, varscan2
- CADPS2 | c.3842G>A p.G1281E | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs745398682; called by muse, mutect2, varscan2
- CAP2 | c.1394G>A p.G465E | Missense Mutation (SNP) | VAF 60/187 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756873512; called by muse, mutect2, varscan2
- CAPN9 | c.1078C>T p.R360C | Missense Mutation (SNP) | VAF 55/194 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs780436701; called by muse, mutect2, varscan2
- CARS1 | c.2057C>T p.P686L | Missense Mutation (SNP) | VAF 41/82 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.382); catalogued as COSV99542507; called by muse, mutect2, varscan2
- CASQ1 | c.892G>A p.E298K | Missense Mutation (SNP) | VAF 68/109 reads (62%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs765926758; called by muse, mutect2, varscan2
- CASR | c.1481G>A p.G494E (on ENST00000490131; = p.G571E on NM_000388.4) | Missense Mutation (SNP) | VAF 144/327 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV56140933, COSV99948616; called by muse, varscan2
- CASR | c.2089G>A p.G697S (on ENST00000490131; = p.G774S on NM_000388.4) | Missense Mutation (SNP) | VAF 116/541 reads (21%) | SIFT tolerated (0.76); PolyPhen probably damaging (0.959); catalogued as CM148668; called by muse, mutect2, varscan2
- CATSPER3 | c.632G>A p.G211E | Missense Mutation (SNP) | VAF 161/267 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1164207126; called by muse, mutect2, varscan2
- CATSPER4 | c.334C>T p.R112C | Missense Mutation (SNP) | VAF 244/783 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs769706025; called by muse, mutect2, varscan2
- CATSPER4 | c.971G>A p.R324Q | Missense Mutation (SNP) | VAF 15/115 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs756980204, COSV58793449; called by muse, mutect2, varscan2
- CBLB | c.1528C>T p.R510C | Missense Mutation (SNP) | VAF 90/181 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1248842712, COSV51437309; called by muse, mutect2, varscan2
- CBLN2 | c.442C>T p.H148Y | Missense Mutation (SNP) | VAF 34/54 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs563682192; called by muse, mutect2, varscan2
- CCDC146 | c.2248G>A p.E750K | Missense Mutation (SNP) | VAF 30/61 reads (49%) | SIFT tolerated (0.09); PolyPhen benign (0.021); catalogued as rs267601574; called by muse, mutect2, varscan2
- CCDC171 | c.868G>A p.E290K | Missense Mutation (SNP) | VAF 13/15 reads (87%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV52635414; called by muse, mutect2, varscan2
- CCDC191 | c.1565C>T p.T522I | Missense Mutation (SNP) | VAF 114/275 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as COSV99878068; called by muse, mutect2, varscan2
- CCDC73 | c.201G>A p.W67* | Nonsense Mutation (SNP) | VAF 8/27 reads (30%) | catalogued as COSV100068000; called by muse, mutect2, varscan2
- CCDC81 | c.154C>T p.P52S | Missense Mutation (SNP) | VAF 26/65 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0.094); catalogued as COSV53577242; called by muse, mutect2, varscan2
- CCDC88C | c.5959G>A p.D1987N | Missense Mutation (SNP) | VAF 40/170 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.226); catalogued as rs765049079, COSV57796118; called by muse, mutect2, varscan2
- CCDC88C | c.2569G>A p.D857N | Missense Mutation (SNP) | VAF 280/668 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs760305711, COSV66239992; called by muse, varscan2
- CCER1 | c.269G>A p.G90E | Missense Mutation (SNP) | VAF 34/119 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.961); catalogued as rs1310736656, COSV62647216; called by muse, mutect2, varscan2
- CCR2 | c.361C>T p.H121Y | Missense Mutation (SNP) | VAF 89/188 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.036); catalogued as COSV99070544; called by muse, mutect2, varscan2
- CCR5 | c.1022G>A p.R341Q | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT tolerated (0.48); PolyPhen benign (0.007); catalogued as rs751446924, COSV52751841; called by muse, mutect2, varscan2
- CCT8L2 | c.647C>T p.S216F | Missense Mutation (SNP) | VAF 88/288 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1470361258, COSV63462543; called by muse, mutect2, varscan2
- CD163 | c.3064G>A p.E1022K | Missense Mutation (SNP) | VAF 48/80 reads (60%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as rs755454282, COSV63137032; called by muse, mutect2
- CD163 | c.2009C>T p.S670L | Missense Mutation (SNP) | VAF 16/23 reads (70%) | SIFT tolerated (0.06); PolyPhen benign (0.345); catalogued as COSV63132504; called by muse, mutect2, varscan2
- CDCA7 | c.1096G>A p.E366K (on ENST00000347703 / NM_145810.3; = p.E445K on NM_031942.5) | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.245); catalogued as COSV60720674; called by muse, mutect2, varscan2
- CDH12 | c.23C>T p.S8F | Missense Mutation (SNP) | VAF 57/95 reads (60%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs1211476604, COSV66420319, COSV66423634; called by muse, mutect2, varscan2
- CDH20 | c.226G>A p.D76N | Missense Mutation (SNP) | VAF 30/112 reads (27%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.905); catalogued as rs367601432, COSV53005591; called by muse, mutect2, varscan2
- CDH9 | c.2197G>A p.D733N | Missense Mutation (SNP) | VAF 41/77 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50258336; called by muse, mutect2, varscan2
- CDH9 | c.805C>T p.P269S | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.009); catalogued as COSV50290079, COSV99142890; called by muse, mutect2, varscan2
- CDON | c.640C>T p.R214C | Missense Mutation (SNP) | VAF 38/103 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.794); catalogued as rs761798261, COSV54995443; called by muse, mutect2, varscan2
- CEACAM5 | c.1159G>A p.D387N | Missense Mutation (SNP) | VAF 89/463 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as rs782351981; called by muse, mutect2, varscan2
- CEBPE | c.116C>T p.S39F | Missense Mutation (SNP) | VAF 256/597 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs751571581; called by muse, mutect2, varscan2
- CECR2 | c.1437G>A p.M479I (on ENST00000342247 / NM_001290047.2; = p.M296I on NM_001290046.1) | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.766); catalogued as rs1299339757; called by muse, varscan2
- CENPE | c.1670C>T p.S557L | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs1287350091, COSV54392180; called by muse, mutect2, varscan2
- CENPT | c.1363C>T p.P455S | Missense Mutation (SNP) | VAF 165/175 reads (94%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.68); catalogued as COSV54651614; called by muse, mutect2, varscan2
- CEP126 | c.2630C>T p.S877L | Missense Mutation (SNP) | VAF 24/50 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.923); catalogued as COSV54824152; called by muse, mutect2, varscan2
- CERS4 | c.718G>A p.D240N | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765990350; called by muse, mutect2, varscan2
- CFAP47 | c.2788G>C p.E930Q | Missense Mutation (SNP) | VAF 76/78 reads (97%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.726); catalogued as COSV52883816, COSV52888611; called by muse, varscan2
- CFAP54 | c.3646C>T p.R1216C | Missense Mutation (SNP) | VAF 16/28 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs1345081413, COSV73047095; called by muse, mutect2, varscan2
- CFAP54 | c.7588C>T p.R2530C | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0.037); catalogued as COSV61573171; called by muse, mutect2, varscan2
- CFAP54 | c.7732C>T p.P2578S | Missense Mutation (SNP) | VAF 59/115 reads (51%) | SIFT tolerated (0.27); PolyPhen benign (0.022); catalogued as rs755471965; called by muse, mutect2, varscan2
- CFAP57 | c.3722C>T p.S1241F (on ENST00000372492 / NM_001378189.1; = p.S1274F on NM_001195831.3) | Missense Mutation (SNP) | VAF 82/145 reads (57%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.067); catalogued as rs537854344, COSV65264569; called by muse, mutect2, varscan2
- CFAP65 | c.3836G>A p.R1279Q | Missense Mutation (SNP) | VAF 90/348 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs761554289; called by muse, varscan2
- CFAP69 | c.2051-1G>A p.X684_splice | Splice Site (SNP) | VAF 28/51 reads (55%) | catalogued as COSV60184655; called by muse, mutect2, varscan2
- CFAP92 | c.1471G>A p.G491R | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1359396974; called by muse, mutect2, varscan2
- CFH | c.2165C>T p.S722L | Missense Mutation (SNP) | VAF 73/117 reads (62%) | SIFT tolerated (0.17); PolyPhen benign (0.209); catalogued as CM1412567, COSV66408121; called by muse, mutect2, varscan2
- CFHR4 | c.467C>T p.S156F (on ENST00000367416 / NM_001201551.2; = p.S157F on NM_001201550.3) | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.958); catalogued as rs544868514; called by muse, mutect2
- CFHR4 | c.1049C>T p.S350F (on ENST00000367416 / NM_001201551.2; = p.S104F on NM_006684.5) | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.92); catalogued as rs1338727661, COSV52229475, COSV99259586; called by muse, mutect2
- CFTR | c.4273G>A p.D1425N | Missense Mutation (SNP) | VAF 91/262 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.02); catalogued as rs867990936, COSV50041151, COSV50113324; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CGNL1 | c.286G>A p.E96K | Missense Mutation (SNP) | VAF 154/350 reads (44%) | SIFT tolerated (0.21); PolyPhen benign (0.057); catalogued as COSV55568259, COSV55570623; called by muse, mutect2, varscan2
- CHEK1 | c.920C>T p.S307F | Missense Mutation (SNP) | VAF 23/50 reads (46%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs1437919116, COSV54025905, COSV99629505; called by muse, mutect2, varscan2
- CHI3L1 | c.914G>A p.G305E | Missense Mutation (SNP) | VAF 55/166 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.985); catalogued as COSV99703935; called by muse, mutect2, varscan2
- CHRM3 | c.68G>A p.S23N | Missense Mutation (SNP) | VAF 118/231 reads (51%) | SIFT tolerated, low confidence (0.94); PolyPhen benign (0.007); catalogued as COSV99697411; called by muse, mutect2, varscan2
- CHRNA4 | c.439G>A p.G147R | Missense Mutation (SNP) | VAF 364/708 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780556996; called by muse, mutect2, varscan2
- CHST4 | c.638C>T p.S213F | Missense Mutation (SNP) | VAF 209/226 reads (92%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs138526504; called by muse, mutect2, varscan2
- CIDEA | c.169G>A p.E57K | Missense Mutation (SNP) | VAF 55/202 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as rs1462538204; called by muse, mutect2, varscan2
- CLCN1 | c.705C>A p.F235L | Missense Mutation (SNP) | VAF 65/152 reads (43%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.944); catalogued as rs760323048, COSV100578290, COSV58367907; called by muse, mutect2, varscan2
- CLCN6 | c.914C>T p.S305F | Missense Mutation (SNP) | VAF 39/354 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.622); catalogued as COSV56743698; called by muse, mutect2, varscan2
- CLEC5A | c.202G>A p.G68R | Missense Mutation (SNP) | VAF 39/103 reads (38%) | SIFT tolerated (0.36); PolyPhen benign (0.142); catalogued as rs1210454350; called by muse, mutect2, varscan2
- CLMN | c.91G>A p.E31K | Missense Mutation (SNP) | VAF 47/134 reads (35%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.964); catalogued as rs770393982; called by muse, mutect2, varscan2
- CMYA5 | c.8126C>T p.P2709L | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV101484061; called by muse, mutect2, varscan2
- CNGA2 | c.1106G>A p.G369E | Missense Mutation (SNP) | VAF 73/78 reads (94%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61703480; called by muse, mutect2, varscan2
- CNGA4 | c.175C>T p.P59S | Missense Mutation (SNP) | VAF 49/114 reads (43%) | SIFT tolerated (0.58); PolyPhen benign (0.031); catalogued as COSV99792116; called by muse, mutect2, varscan2
- CNGB1 | c.3277G>A p.E1093K | Missense Mutation (SNP) | VAF 486/538 reads (90%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as COSV51906971; called by muse, mutect2, varscan2
- CNGB3 | c.1172G>A p.G391E | Missense Mutation (SNP) | VAF 40/76 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs267602030; called by muse, mutect2, varscan2
- CNGB3 | c.901C>T p.Q301* | Nonsense Mutation (SNP) | VAF 61/111 reads (55%) | catalogued as rs868249629, COSV60697861; called by muse, mutect2, varscan2
- CNST | c.1133C>T p.S378F | Missense Mutation (SNP) | VAF 83/228 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.329); catalogued as COSV100830018; called by muse, mutect2, varscan2
- CNTN3 | c.2098C>T p.P700S | Missense Mutation (SNP) | VAF 33/71 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55187917; called by muse, mutect2, varscan2
- CNTN3 | c.491C>T p.S164L | Missense Mutation (SNP) | VAF 104/214 reads (49%) | SIFT tolerated (0.75); PolyPhen possibly damaging (0.857); catalogued as rs752936529, COSV55176589; called by muse, mutect2, varscan2
- CNTN4 | c.3014C>T p.S1005L | Missense Mutation (SNP) | VAF 66/147 reads (45%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs753714750, COSV61867614; called by muse, mutect2, varscan2
- CNTN5 | c.1192G>A p.D398N | Missense Mutation (SNP) | VAF 40/90 reads (44%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.984); catalogued as COSV99681570; called by muse, mutect2, varscan2
- CNTNAP2 | c.1751G>A p.G584E | Missense Mutation (SNP) | VAF 47/92 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as rs772138449, COSV62170132; called by muse, varscan2
- CNTNAP2 | c.3730C>T p.P1244S | Missense Mutation (SNP) | VAF 44/115 reads (38%) | SIFT tolerated (0.66); PolyPhen benign (0.003); catalogued as COSV62145718; called by muse, mutect2, varscan2
- CNTNAP5 | c.938C>T p.P313L | Missense Mutation (SNP) | VAF 26/39 reads (67%) | SIFT tolerated (0.14); PolyPhen probably damaging (1); catalogued as COSV70511674; called by muse, mutect2, varscan2
- COL11A2 | c.2650C>T p.P884S (on ENST00000341947 / NM_080680.3; = p.P777S on NM_080679.2) | Missense Mutation (SNP) | VAF 103/231 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs756752990; called by muse, mutect2, varscan2
- COL12A1 | c.8170C>T p.P2724S | Missense Mutation (SNP) | VAF 32/120 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs766567574; called by muse, mutect2, varscan2
- COL18A1 | c.3358C>T p.P1120S (on ENST00000359759 / NM_130444.3; = p.P885S on NM_030582.4) | Missense Mutation (SNP) | VAF 412/674 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs765760874; called by muse, varscan2
- COL1A1 | c.3068C>T p.S1023F | Missense Mutation (SNP) | VAF 306/652 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.124); catalogued as COSV56804225; called by muse, varscan2
- COL28A1 | c.3112C>T p.P1038S | Missense Mutation (SNP) | VAF 33/102 reads (32%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as rs1247823473; called by muse, mutect2, varscan2
- COL2A1 | c.3983C>T p.P1328L | Missense Mutation (SNP) | VAF 91/240 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.041); catalogued as rs1217363397; called by muse, mutect2, varscan2
- COL2A1 | c.817-1G>A p.X273_splice | Splice Site (SNP) | VAF 240/416 reads (58%) | catalogued as CS1210179; called by muse, mutect2, varscan2
- COL4A4 | c.3943C>T p.P1315S | Missense Mutation (SNP) | VAF 55/206 reads (27%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.999); catalogued as COSV61630789; called by muse, mutect2, varscan2
- COL4A4 | c.1891G>A p.G631R | Missense Mutation (SNP) | VAF 208/353 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100307616; called by muse, varscan2
- COL4A4 | c.1837G>A p.G613R | Missense Mutation (SNP) | VAF 76/281 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM095034, COSV61636654; called by muse, varscan2
- COL4A5 | c.2831G>A p.G944E | Missense Mutation (SNP) | VAF 96/107 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CD148146; called by muse, mutect2, varscan2
- COL5A1 | c.1291G>T p.G431W | Missense Mutation (SNP) | VAF 136/152 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65672645; called by muse, mutect2, varscan2
- COL6A3 | c.8344G>A p.E2782K | Missense Mutation (SNP) | VAF 138/504 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.927); catalogued as rs794727603; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL6A3 | c.203C>T p.S68F | Missense Mutation (SNP) | VAF 48/67 reads (72%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.694); catalogued as COSV55113675; called by muse, mutect2, varscan2
- COL6A6 | c.2017G>A p.E673K | Missense Mutation (SNP) | VAF 133/280 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.052); catalogued as COSV100651116; called by muse, mutect2, varscan2
- COL7A1 | c.7559G>A p.G2520E | Missense Mutation (SNP) | VAF 266/693 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM103726; called by muse, mutect2, varscan2
- COL8A1 | c.1772G>A p.G591E | Missense Mutation (SNP) | VAF 88/219 reads (40%) | SIFT tolerated (0.18); PolyPhen benign (0.037); catalogued as COSV53730450; called by muse, varscan2
- COL8A1 | c.1943C>T p.P648L | Missense Mutation (SNP) | VAF 142/313 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.228); catalogued as rs763974579, COSV99657173; called by muse, varscan2
- CPEB2 | c.1078G>A p.G360R | Missense Mutation (SNP) | VAF 47/70 reads (67%) | SIFT deleterious, low confidence (0.01); catalogued as rs943210476; called by muse, varscan2
- CPNE3 | c.451G>A p.D151N | Missense Mutation (SNP) | VAF 22/41 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1342567625; called by muse, mutect2, varscan2
- CPO | c.590G>A p.R197K | Missense Mutation (SNP) | VAF 42/110 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV55941155; called by muse, mutect2, varscan2
- CPS1 | c.2231G>A p.G744E | Missense Mutation (SNP) | VAF 106/168 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1218362638; called by muse, mutect2, varscan2
- CR1 | c.4174C>T p.R1392C | Missense Mutation (SNP) | VAF 48/166 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.791); catalogued as rs766544117, COSV65457250; called by muse, mutect2
- CR1L | c.763G>A p.E255K | Missense Mutation (SNP) | VAF 206/360 reads (57%) | SIFT tolerated (0.37); PolyPhen benign (0.348); catalogued as rs1172263771, COSV54322718; called by muse, mutect2, varscan2
- CROCC2 | c.2890G>A p.A964T | Missense Mutation (SNP) | VAF 111/385 reads (29%) | SIFT tolerated (0.12); PolyPhen benign (0.178); catalogued as rs1354924547; called by muse, mutect2, varscan2
- CRYBG2 | c.2360G>A p.R787Q | Missense Mutation (SNP) | VAF 15/78 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs756237085; called by muse, mutect2, varscan2
- CSMD1 | c.9977G>A p.G3326E (on ENST00000520002; = p.G3325E on NM_033225.6) | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV59286808; called by muse, varscan2
- CSMD1 | c.3847C>T p.H1283Y (on ENST00000520002; = p.H1282Y on NM_033225.6) | Missense Mutation (SNP) | VAF 28/94 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.284); catalogued as rs1482502744; called by muse, mutect2, varscan2
- CSMD1 | c.3229C>T p.R1077C (on ENST00000520002; = p.R1076C on NM_033225.6) | Missense Mutation (SNP) | VAF 32/168 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs867742507, COSV59279573, COSV59288383; called by muse, varscan2
- CSMD1 | c.3181C>T p.H1061Y (on ENST00000520002; = p.H1060Y on NM_033225.6) | Missense Mutation (SNP) | VAF 29/142 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.182); catalogued as COSV59325986; called by muse, varscan2
- CSMD2 | c.3773G>A p.R1258Q | Missense Mutation (SNP) | VAF 91/201 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs906640660, COSV53932581; called by muse, mutect2, varscan2
- CSMD2 | c.2080C>T p.P694S | Missense Mutation (SNP) | VAF 32/246 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53935040, COSV53938795; called by muse, mutect2
- CSMD3 | c.5531C>T p.S1844L (on ENST00000297405 / NM_001363185.1; = p.S1740L on NM_052900.3) | Missense Mutation (SNP) | VAF 65/122 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.685); catalogued as COSV52104107; called by muse, varscan2
- CSMD3 | c.1058C>G p.S353C | Missense Mutation (SNP) | VAF 46/165 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); catalogued as COSV99822292; called by muse, mutect2, varscan2
- CTDP1 | c.1795C>T p.R599C | Missense Mutation (SNP) | VAF 409/685 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1305258889; called by muse, mutect2, varscan2
- CTNNA2 | c.217G>A p.E73K | Missense Mutation (SNP) | VAF 36/119 reads (30%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.575); catalogued as rs776430147, COSV63560645; called by muse, mutect2, varscan2
- CUBN | c.10492C>T p.R3498C | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.809); catalogued as rs181848786, COSV64716773; called by muse, mutect2, varscan2
- CUBN | c.5314C>T p.P1772S | Missense Mutation (SNP) | VAF 61/185 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV64718485; called by muse, mutect2, varscan2
- CUX2 | c.1225C>T p.L409F | Missense Mutation (SNP) | VAF 149/259 reads (58%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.823); catalogued as COSV55627371; called by muse, mutect2, varscan2
- CUX2 | c.2551G>A p.E851K | Missense Mutation (SNP) | VAF 53/178 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.2); catalogued as rs1421401837; called by muse, varscan2
- CXCR1 | c.400G>A p.D134N | Missense Mutation (SNP) | VAF 89/247 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99826308; called by muse, mutect2, varscan2
- CYLC2 | c.541G>A p.E181K | Missense Mutation (SNP) | VAF 23/28 reads (82%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV66336737, COSV66337270; called by muse, mutect2, varscan2
- CYLD | c.992C>T p.S331L | Missense Mutation (SNP) | VAF 159/185 reads (86%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs1231850997; called by muse, mutect2, varscan2
- CYP2E1 | c.1050G>A p.M350I | Missense Mutation (SNP) | VAF 44/139 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.074); catalogued as COSV53315170; called by muse, mutect2, varscan2
- CYP4A22 | c.1474G>A p.A492T | Missense Mutation (SNP) | VAF 98/211 reads (46%) | SIFT tolerated (0.05); PolyPhen benign (0.023); catalogued as COSV53740063; called by muse, mutect2, varscan2
- CYP4F8 | c.323G>A p.R108Q | Missense Mutation (SNP) | VAF 338/665 reads (51%) | SIFT tolerated (0.11); PolyPhen benign (0.087); catalogued as rs773731200, COSV57854178; called by muse, mutect2, varscan2
- CYP4Z1 | c.880G>A p.E294K | Missense Mutation (SNP) | VAF 66/182 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.985); catalogued as rs754866665, COSV61963828; called by muse, mutect2, varscan2
- DACH1 | c.1295C>T p.P432L (on ENST00000619232 / NM_001366712.1; = p.P380L on NM_080759.6) | Missense Mutation (SNP) | VAF 55/65 reads (85%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100498967; called by muse, mutect2, varscan2
- DAGLA | c.2609C>T p.P870L | Missense Mutation (SNP) | VAF 174/430 reads (40%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.011); catalogued as COSV99944053; called by muse, mutect2, varscan2
- DAO | c.109G>A p.D37N | Missense Mutation (SNP) | VAF 116/207 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99948380; called by muse, mutect2, varscan2
- DBNDD2 | c.139C>T p.R47C | Missense Mutation (SNP) | VAF 38/78 reads (49%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.685); catalogued as rs573669747; called by muse, varscan2
- DCAF7 | c.350C>T p.S117F | Missense Mutation (SNP) | VAF 35/90 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.386); catalogued as COSV100177599; called by muse, mutect2, varscan2
- DCAF8L1 | c.431C>T p.S144F | Missense Mutation (SNP) | VAF 154/172 reads (90%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.635); catalogued as rs1355549463, COSV71595515; called by muse, mutect2, varscan2
- DCANP1 | c.296C>T p.S99L | Missense Mutation (SNP) | VAF 44/144 reads (31%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0); catalogued as rs376193776; called by muse, mutect2, varscan2
- DCC | c.2413G>A p.G805R | Missense Mutation (SNP) | VAF 29/117 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59100092; called by muse, mutect2, varscan2
- DCP1A | c.767C>T p.S256L | Missense Mutation (SNP) | VAF 52/250 reads (21%) | SIFT tolerated (0.74); PolyPhen benign (0.011); catalogued as COSV99588254; called by muse, mutect2, varscan2
- DDHD1 | c.2009C>T p.P670L (on ENST00000323669; = p.P867L on NM_030637.3) | Missense Mutation (SNP) | VAF 30/61 reads (49%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.017); catalogued as rs749084227; called by muse, mutect2, varscan2
- DDR1 | c.1765C>T p.P589S (on ENST00000324771; = p.P552S on NM_001954.4) | Missense Mutation (SNP) | VAF 37/58 reads (64%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs754549769; called by muse, mutect2, varscan2
- DEDD2 | c.536C>T p.P179L | Missense Mutation (SNP) | VAF 105/156 reads (67%) | SIFT tolerated (0.31); PolyPhen benign (0.036); catalogued as rs749412518; called by muse, mutect2, varscan2
- DEGS2 | c.521C>T p.P174L | Missense Mutation (SNP) | VAF 86/199 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.109); catalogued as rs1202646721; called by muse, mutect2, varscan2
- DENND4B | c.22C>T p.R8W | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.825); catalogued as rs773645375; called by muse, mutect2, varscan2
- DGKB | c.2390G>A p.R797K | Missense Mutation (SNP) | VAF 42/112 reads (38%) | SIFT tolerated (0.69); PolyPhen benign (0.001); catalogued as COSV51763428, COSV51814009; called by muse, mutect2, varscan2
- DGKD | c.2900C>T p.S967F (on ENST00000264057 / NM_152879.3; = p.S923F on NM_003648.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 88/342 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as rs776145724; called by muse, mutect2, varscan2
- DGKH | c.2351C>T p.S784L | Missense Mutation (SNP) | VAF 12/12 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV54929583; called by muse, mutect2, varscan2
- DGLUCY | c.322G>A p.E108K | Missense Mutation (SNP) | VAF 203/433 reads (47%) | SIFT tolerated (0.47); PolyPhen benign (0.321); catalogued as rs1349532323, COSV54088323; called by muse, mutect2, varscan2
- DKK2 | c.293C>T p.S98L | Missense Mutation (SNP) | VAF 78/139 reads (56%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.988); catalogued as rs267599976, COSV53403075, COSV99569303; called by muse, mutect2, varscan2
- DLEC1 | c.5059G>A p.V1687I | Missense Mutation (SNP) | VAF 121/300 reads (40%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.462); catalogued as rs760388697; called by muse, mutect2, varscan2
- DLG2 | c.2150G>A p.R717Q | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1362746040, COSV54621849, COSV99719564; called by muse, mutect2
- DLG5 | c.3419C>T p.P1140L | Missense Mutation (SNP) | VAF 68/161 reads (42%) | SIFT tolerated (0.66); PolyPhen benign (0.023); catalogued as rs201245614, COSV100967950, COSV64949922; called by muse, mutect2, varscan2
- DMBT1 | c.284G>A p.G95E | Missense Mutation (SNP) | VAF 57/130 reads (44%) | SIFT tolerated (0.63); PolyPhen possibly damaging (0.79); catalogued as rs1428450401, COSV100353154; called by muse, mutect2, varscan2
- DMBT1 | c.7160C>T p.S2387F (on ENST00000338354 / NM_001377530.1; = p.S1630F on NM_004406.3) | Missense Mutation (SNP) | VAF 58/124 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV57535809, COSV57541035; called by muse, mutect2, varscan2
- DNAH10 | c.4687G>A p.E1563K (on ENST00000409039; = p.E1502K on NM_207437.3) | Missense Mutation (SNP) | VAF 38/71 reads (54%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.571); catalogued as COSV68996965; called by muse, varscan2
- DNAH10 | c.10648G>A p.D3550N (on ENST00000409039; = p.D3489N on NM_207437.3) | Missense Mutation (SNP) | VAF 68/122 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV68988348; called by muse, mutect2, varscan2
- DNAH5 | c.9430G>A p.E3144K | Missense Mutation (SNP) | VAF 34/153 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.055); catalogued as COSV54205540; called by muse, mutect2, varscan2
- DNAH5 | c.8644G>A p.A2882T | Missense Mutation (SNP) | VAF 52/102 reads (51%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1169466292; called by muse, mutect2, varscan2
- DNAH5 | c.1372A>G p.N458D | Missense Mutation (SNP) | VAF 56/93 reads (60%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as rs1561560210; called by muse, varscan2
- DNAH7 | c.7132G>A p.E2378K | Missense Mutation (SNP) | VAF 39/158 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.521); catalogued as COSV56785673; called by muse, mutect2, varscan2
- DNAH8 | c.8420G>A p.R2807Q | Missense Mutation (SNP) | VAF 68/166 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1223225126, COSV59424119; called by muse, mutect2, varscan2
- DNHD1 | c.656C>T p.P219L | Missense Mutation (SNP) | VAF 63/162 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as rs1474463927; called by muse, mutect2, varscan2
- DOP1B | c.2980C>T p.R994C | Missense Mutation (SNP) | VAF 80/303 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs560805511; called by muse, mutect2, varscan2
- DPAGT1 | c.671C>T p.S224F | Missense Mutation (SNP) | VAF 57/158 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751590922; ClinVar: uncertain significance; called by mutect2, varscan2
- DPPA2 | c.511G>A p.E171K | Missense Mutation (SNP) | VAF 107/289 reads (37%) | SIFT tolerated (0.27); PolyPhen benign (0.018); catalogued as rs760934559; called by muse, mutect2, varscan2
- DSC2 | c.1810C>T p.H604Y | Missense Mutation (SNP) | VAF 142/230 reads (62%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV51864942; called by muse, mutect2, varscan2
- DSCAML1 | c.1285G>A p.E429K (on ENST00000321322; = p.E369K on NM_020693.4) | Missense Mutation (SNP) | VAF 179/471 reads (38%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.677); catalogued as rs777606240, COSV58399468; called by muse, mutect2, varscan2
- DSEL | c.2587C>T p.P863S | Missense Mutation (SNP) | VAF 61/85 reads (72%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV100025391; called by muse, mutect2, varscan2
- DSG3 | c.700C>T p.R234C | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.806); catalogued as rs772960249, COSV57124134; called by muse, mutect2, varscan2
- DYNC1H1 | c.11050C>T p.P3684S | Missense Mutation (SNP) | VAF 174/420 reads (41%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.462); catalogued as rs267603883; called by muse, mutect2, varscan2
- EBF2 | c.493G>A p.E165K | Missense Mutation (SNP) | VAF 81/165 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.109); catalogued as COSV68775824; called by muse, mutect2, varscan2
- EBLN2 | c.159G>C p.K53N | Missense Mutation (SNP) | VAF 18/121 reads (15%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as rs1374595572; called by muse, mutect2, varscan2
- ECEL1 | c.1664G>A p.R555Q | Missense Mutation (SNP) | VAF 43/199 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.208); catalogued as rs769439158; called by muse, mutect2, varscan2
- EDARADD | c.508C>T p.R170W (on ENST00000334232 / NM_145861.4; = p.R160W on NM_080738.4) | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM138359, COSV62064302, COSV62065263; called by muse, mutect2, varscan2
- EFCAB5 | c.1285C>T p.R429* | Nonsense Mutation (SNP) | VAF 71/77 reads (92%) | catalogued as rs374541486; called by muse, mutect2, varscan2
- EHD3 | c.308G>A p.G103E | Missense Mutation (SNP) | VAF 50/249 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs111827178; called by muse, mutect2, varscan2
- ELL | c.460C>T p.R154C | Missense Mutation (SNP) | VAF 91/123 reads (74%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.95); catalogued as rs746959534; called by muse, mutect2, varscan2
- ELOVL4 | c.647G>A p.R216Q | Missense Mutation (SNP) | VAF 79/149 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as rs776107074; called by muse, mutect2, varscan2
- EMID1 | c.466-1G>A p.X156_splice | Splice Site (SNP) | VAF 38/104 reads (37%) | catalogued as COSV61830294, COSV61830526; called by muse, mutect2, varscan2
- EML1 | c.383+1G>A p.X128_splice | Splice Site (SNP) | VAF 65/148 reads (44%) | catalogued as COSV51743847; called by muse, mutect2
- EML6 | c.4841G>A p.G1614E | Missense Mutation (SNP) | VAF 32/90 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV62872636; called by muse, mutect2
- ENC1 | c.841G>A p.G281S | Missense Mutation (SNP) | VAF 119/199 reads (60%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.981); catalogued as rs1383586342; called by muse, mutect2, varscan2
- ENTPD1 | c.929C>T p.P310L | Missense Mutation (SNP) | VAF 61/151 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.872); catalogued as COSV64604070; called by muse, mutect2, varscan2
- EPB41L4A | c.1622C>T p.S541L | Missense Mutation (SNP) | VAF 106/165 reads (64%) | SIFT tolerated (0.05); PolyPhen benign (0.426); catalogued as rs1186499825, COSV54868652; called by muse, mutect2, varscan2
- EPB41L4A | c.605C>T p.S202F | Missense Mutation (SNP) | VAF 54/201 reads (27%) | SIFT tolerated (0.24); PolyPhen benign (0.361); catalogued as rs1230326070; called by muse, mutect2, varscan2
- EPB41L5 | c.1004G>A p.R335Q | Missense Mutation (SNP) | VAF 81/132 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs369050670; called by muse, mutect2, varscan2
- EPHA4 | c.982C>T p.P328S | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.539); catalogued as rs1420416308; called by muse, mutect2, varscan2
- EPHA6 | c.2612G>A p.G871E (on ENST00000389672 / NM_001080448.3; = p.G263E on NM_173655.4) | Missense Mutation (SNP) | VAF 71/146 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV67595266; called by muse, mutect2, varscan2
- EPS15L1 | c.2185C>T p.P729S | Missense Mutation (SNP) | VAF 81/157 reads (52%) | SIFT deleterious (0.04); PolyPhen benign (0.424); catalogued as COSV50167130; called by muse, mutect2, varscan2
- EPS8L3 | c.185G>A p.R62Q | Missense Mutation (SNP) | VAF 189/212 reads (89%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.874); catalogued as rs202174892, COSV100719698; called by muse, mutect2, varscan2
- ERBB4 | c.884-1G>A p.X295_splice | Splice Site (SNP) | VAF 63/115 reads (55%) | catalogued as COSV53514071; called by muse, mutect2, varscan2
- ERBB4 | c.316C>T p.R106C | Missense Mutation (SNP) | VAF 57/103 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751175543, COSV53515716; called by muse, mutect2, varscan2
- ERCC8 | c.802C>T p.R268* | Nonsense Mutation (SNP) | VAF 86/148 reads (58%) | catalogued as rs370657735; called by muse, mutect2, varscan2
- ERICH3 | c.2027G>A p.G676E | Missense Mutation (SNP) | VAF 181/195 reads (93%) | SIFT tolerated (0.07); PolyPhen benign (0.017); catalogued as COSV58614267; called by muse, mutect2, varscan2
- ERICH5 | c.938G>A p.R313Q | Missense Mutation (SNP) | VAF 30/46 reads (65%) | SIFT deleterious (0.02); PolyPhen benign (0.039); catalogued as rs762941709, COSV59315425; called by muse, mutect2, varscan2
- EVC | c.2738C>T p.P913L | Missense Mutation (SNP) | VAF 174/615 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs148823298, COSV53829222; called by muse, mutect2, varscan2
- EXD1 | c.1120C>T p.H374Y | Missense Mutation (SNP) | VAF 54/105 reads (51%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.133); catalogued as rs1232702635; called by muse, mutect2, varscan2
- EXTL1 | c.1244C>T p.P415L | Missense Mutation (SNP) | VAF 18/130 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.41); catalogued as COSV65337292; called by muse, mutect2, varscan2
- EYS | c.3197C>T p.S1066L | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT tolerated (0.68); PolyPhen benign (0.003); catalogued as COSV65509032; called by muse, mutect2, varscan2
- EYS | c.1484G>A p.G495E | Missense Mutation (SNP) | VAF 109/275 reads (40%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs1263410250, COSV60999903; called by muse, mutect2, varscan2
- F2RL1 | c.104G>A p.G35E | Missense Mutation (SNP) | VAF 22/32 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs866400242; called by muse, mutect2, varscan2
- F5 | c.6164G>A p.R2055Q | Missense Mutation (SNP) | VAF 59/124 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs886045542, COSV100889208; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- F8 | c.6038G>A p.G2013E | Missense Mutation (SNP) | VAF 133/142 reads (94%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM161996; called by muse, mutect2, varscan2
- FAAH | c.1507C>T p.P503S | Missense Mutation (SNP) | VAF 431/731 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1334134656; called by muse, mutect2, varscan2
- FADS6 | c.510G>A p.W170* | Nonsense Mutation (SNP) | VAF 215/489 reads (44%) | catalogued as rs763385048, COSV59603323; called by muse, mutect2, varscan2
- FAM107B | c.377C>T p.S126F | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.471); catalogued as rs1414893816; called by muse, mutect2, varscan2
- FAM177A1 | c.175C>T p.H59Y (on ENST00000382406 / NM_001289022.2; = p.H82Y on NM_173607.5) | Missense Mutation (SNP) | VAF 90/188 reads (48%) | SIFT tolerated (0.18); PolyPhen benign (0.301); catalogued as rs1388865111; called by muse, mutect2, varscan2
- FAM184B | c.2834G>A p.R945Q | Missense Mutation (SNP) | VAF 56/103 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs143581443, COSV52846597; called by muse, mutect2, varscan2
- FAM209A | c.133C>T p.R45W | Missense Mutation (SNP) | VAF 276/607 reads (45%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.978); catalogued as rs778119401, COSV54766435; called by muse, varscan2
- FAM83B | c.245C>T p.S82F | Missense Mutation (SNP) | VAF 45/145 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.018); catalogued as COSV60925285; called by muse, mutect2, varscan2
- FAP | c.847C>T p.P283S | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.676); catalogued as rs1434177084, COSV51861890; called by muse, mutect2, varscan2
- FASTKD1 | c.800C>T p.S267F | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.11); PolyPhen benign (0.014); catalogued as rs1452432731; called by muse, mutect2, varscan2
- FAT2 | c.11488G>A p.E3830K | Missense Mutation (SNP) | VAF 71/115 reads (62%) | SIFT tolerated (0.93); PolyPhen benign (0.294); catalogued as rs867387324; called by muse, mutect2, varscan2
- FAT4 | c.6382G>A p.D2128N | Missense Mutation (SNP) | VAF 27/92 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV58682891; called by muse, mutect2, varscan2
- FAT4 | c.10093C>T p.R3365* | Nonsense Mutation (SNP) | VAF 29/110 reads (26%) | catalogued as COSV58701375; called by muse, mutect2, varscan2
- FAT4 | c.10507G>A p.E3503K | Missense Mutation (SNP) | VAF 79/137 reads (58%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); catalogued as COSV58674148; called by muse, mutect2, varscan2
- FAT4 | c.13801C>T p.P4601S | Missense Mutation (SNP) | VAF 53/169 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV58685997; called by muse, mutect2, varscan2
- FAT4 | c.14189G>A p.G4730D | Missense Mutation (SNP) | VAF 50/220 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0.29); catalogued as rs758977058, COSV58683034; called by muse, mutect2, varscan2
- FBLN5 | c.473G>T p.G158V | Missense Mutation (SNP) | VAF 360/766 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50902259, COSV99970094; called by muse, varscan2
- FBN2 | c.2926G>A p.G976R | Missense Mutation (SNP) | VAF 75/301 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.802); catalogued as COSV99329246; called by muse, mutect2, varscan2
- FBXO40 | c.1079G>A p.R360Q | Missense Mutation (SNP) | VAF 79/166 reads (48%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as rs550316946; called by muse, mutect2, varscan2
- FBXO47 | c.125G>A p.G42E | Missense Mutation (SNP) | VAF 56/112 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs771301473; called by muse, mutect2, varscan2
- FBXW11 | c.1343G>A p.C448Y | Missense Mutation (SNP) | VAF 23/124 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51604937; called by muse, mutect2, varscan2
- FCGBP | c.1973C>T p.P658L | Missense Mutation (SNP) | VAF 63/249 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs975508612; called by muse, mutect2, varscan2
- FCN1 | c.882G>A p.M294I | Missense Mutation (SNP) | VAF 234/269 reads (87%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV65662611; called by muse, mutect2, varscan2
- FCRL1 | c.664G>A p.E222K | Missense Mutation (SNP) | VAF 69/204 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.072); catalogued as rs148190948; called by muse, mutect2, varscan2
- FCSK | c.3017G>A p.R1006Q | Missense Mutation (SNP) | VAF 382/423 reads (90%) | SIFT tolerated (0.12); PolyPhen benign (0.022); catalogued as rs372940483; called by muse, mutect2, varscan2
- FER | c.535C>T p.H179Y | Missense Mutation (SNP) | VAF 108/178 reads (61%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.651); catalogued as rs1167365517; called by muse, mutect2, varscan2
- FEZF2 | c.799G>A p.G267R | Missense Mutation (SNP) | VAF 252/576 reads (44%) | SIFT tolerated (0.58); PolyPhen benign (0.23); catalogued as rs1263322479; called by muse, mutect2, varscan2
- FGD6 | c.4254G>A p.Q1418= | Splice Region (SNP) | VAF 16/24 reads (67%) | catalogued as rs1325702518; called by muse, mutect2, varscan2
- FGD6 | c.4025G>A p.R1342K | Missense Mutation (SNP) | VAF 46/112 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.965); catalogued as rs1331604826; called by muse, varscan2
- FGF13 | c.631G>A p.D211N | Missense Mutation (SNP) | VAF 92/99 reads (93%) | SIFT tolerated (0.15); PolyPhen benign (0.051); catalogued as rs1264974671, COSV59542497; called by muse, mutect2, varscan2
- FGF2 | c.785G>A p.R262Q | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.955); catalogued as COSV52649399; called by muse, mutect2, varscan2
- FGF3 | c.355G>A p.E119K | Missense Mutation (SNP) | VAF 16/39 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61925354; called by muse, mutect2, varscan2
- FGF6 | c.223G>A p.E75K | Missense Mutation (SNP) | VAF 238/397 reads (60%) | SIFT deleterious (0.05); PolyPhen benign (0.043); catalogued as rs1448230216, COSV57403639; called by muse, mutect2, varscan2
- FGF8 | c.697C>T p.R233* (on ENST00000344255 / NM_033164.4; = p.R215* on NM_006119.6) | Nonsense Mutation (SNP) | VAF 45/96 reads (47%) | catalogued as rs774950983, COSV60142790; called by muse, mutect2, varscan2
- FGR | c.488A>G p.N163S | Missense Mutation (SNP) | VAF 96/368 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.378); catalogued as COSV64969830; called by muse, mutect2, varscan2
- FLG | c.1484C>T p.S495L | Missense Mutation (SNP) | VAF 320/562 reads (57%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); catalogued as rs139321371, COSV100910484; called by muse, mutect2, varscan2
- FLI1 | c.385+7C>T | Splice Region (SNP) | VAF 83/181 reads (46%) | catalogued as rs757543142, COSV55648172; ClinVar: likely benign; called by muse, mutect2, varscan2
- FLI1 | c.442G>A p.E148K | Missense Mutation (SNP) | VAF 57/150 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.313); catalogued as COSV55645873; called by muse, mutect2, varscan2
- FLT1 | c.2407G>A p.E803K | Missense Mutation (SNP) | VAF 89/106 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV56724713; called by muse, mutect2, varscan2
- FMN2 | c.1892C>G p.P631R | Missense Mutation (SNP) | VAF 47/75 reads (63%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.467); catalogued as COSV60424631, COSV60452215; called by muse, mutect2, varscan2
- FMN2 | c.3526C>T p.P1176S | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated, low confidence (0.61); PolyPhen probably damaging (0.95); catalogued as rs549087270; called by muse, mutect2, varscan2
- FNDC7 | c.2194G>A p.E732K | Missense Mutation (SNP) | VAF 88/99 reads (89%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV54752224; called by muse, mutect2, varscan2
- FOLH1 | c.1814G>T p.R605I | Missense Mutation (SNP) | VAF 34/92 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as COSV57050899, COSV99923355; called by muse, varscan2
- FOXRED2 | c.718C>T p.H240Y | Missense Mutation (SNP) | VAF 196/347 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs376532267; called by muse, mutect2, varscan2
- FRMPD3 | c.2660C>T p.P887L | Missense Mutation (SNP) | VAF 247/262 reads (94%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.041); catalogued as rs751767042, COSV52190734; called by muse, mutect2, varscan2
- FRY | c.4031G>A p.R1344Q | Missense Mutation (SNP) | VAF 101/250 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.199); catalogued as rs778464691; called by muse, mutect2, varscan2
- FSIP2 | c.10132G>A p.E3378K | Missense Mutation (SNP) | VAF 28/48 reads (58%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs760834720, COSV58079866; called by muse, mutect2, varscan2
- FSIP2 | c.12766G>A p.E4256K | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.018); catalogued as rs963551196, COSV104420951; called by muse, mutect2, varscan2
- FSIP2 | c.17308G>A p.D5770N | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as rs1479991993, COSV100555547; called by muse, mutect2, varscan2
- FSTL5 | c.523C>T p.R175W | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs779449215, COSV60198887; called by muse, mutect2, varscan2
- GABRA3 | c.373G>A p.E125K | Missense Mutation (SNP) | VAF 165/185 reads (89%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.992); catalogued as rs75040827; called by muse, mutect2, varscan2
- GABRA6 | c.347C>T p.T116I | Missense Mutation (SNP) | VAF 55/201 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50893282; called by muse, mutect2, varscan2
- GABRG1 | c.98G>A p.G33E | Missense Mutation (SNP) | VAF 66/115 reads (57%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.994); catalogued as COSV54950313; called by muse, mutect2, varscan2
- GABRG2 | c.791G>A p.R264Q (on ENST00000361925 / NM_001375343.1; = p.R224Q on NM_000816.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 86/174 reads (49%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.481); catalogued as rs776456366, COSV62716042; called by muse, mutect2, varscan2
- GABRR3 | c.196C>T p.H66Y | Missense Mutation (SNP) | VAF 46/108 reads (43%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.625); catalogued as rs1359006680, COSV101512309; called by muse, mutect2, varscan2
- GAL3ST4 | c.547C>T p.P183S | Missense Mutation (SNP) | VAF 78/187 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs751857243; called by muse, mutect2, varscan2
- GATA1 | c.919C>T p.R307C | Missense Mutation (SNP) | VAF 292/310 reads (94%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1057518396, COSV100936648, COSV100936904; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GATA3 | c.346C>T p.P116S | Missense Mutation (SNP) | VAF 43/97 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.186); catalogued as rs1440490623; called by muse, mutect2, varscan2
- GCNA | c.1510G>A p.E504K | Missense Mutation (SNP) | VAF 26/31 reads (84%) | SIFT deleterious (0.04); PolyPhen benign (0.432); catalogued as rs531702754; called by muse, mutect2, varscan2
- GCNT4 | c.265G>A p.E89K | Missense Mutation (SNP) | VAF 29/111 reads (26%) | SIFT tolerated (0.22); PolyPhen benign (0.444); catalogued as rs752610975; called by muse, mutect2, varscan2
- GFAP | c.52G>A p.G18R | Missense Mutation (SNP) | VAF 124/263 reads (47%) | SIFT tolerated (0.37); PolyPhen benign (0.161); catalogued as rs1354251613; called by muse, varscan2
- GFRAL | c.46G>A p.E16K | Missense Mutation (SNP) | VAF 28/49 reads (57%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as rs868599487, COSV61228767, COSV61234756; called by muse, mutect2, varscan2
- GFRAL | c.951C>T p.F317= | Splice Region (SNP) | VAF 31/53 reads (58%) | catalogued as COSV99080205; called by muse, mutect2, varscan2
- GFRAL | c.1127C>T p.S376F | Missense Mutation (SNP) | VAF 44/73 reads (60%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV61231156; called by muse, mutect2, varscan2
- GIGYF2 | c.1105G>A p.E369K | Missense Mutation (SNP) | VAF 68/121 reads (56%) | SIFT tolerated (0.43); PolyPhen benign (0.021); catalogued as rs770408139; called by muse, mutect2, varscan2
- GLI1 | c.628C>T p.P210S | Missense Mutation (SNP) | VAF 54/154 reads (35%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV57358975, COSV57362298; called by muse, mutect2, varscan2
- GLIS3 | c.1744C>T p.P582S | Missense Mutation (SNP) | VAF 154/172 reads (90%) | SIFT tolerated (0.18); PolyPhen benign (0.03); catalogued as COSV100174392; called by muse, mutect2, varscan2
- GLOD5 | c.167C>T p.S56F | Missense Mutation (SNP) | VAF 76/77 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57489237; called by muse, mutect2, varscan2
- GMIP | c.1358C>T p.S453L | Missense Mutation (SNP) | VAF 79/525 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.163); catalogued as rs1290915582, COSV52556334; called by muse, mutect2, varscan2
- GNA14 | c.196G>A p.E66K | Missense Mutation (SNP) | VAF 149/166 reads (90%) | SIFT tolerated (0.08); PolyPhen benign (0.111); catalogued as rs756624939, COSV59020348; called by muse, mutect2, varscan2
- GNAI2 | c.545C>T p.T182I | Missense Mutation (SNP) | VAF 147/366 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56493295; called by muse, mutect2, varscan2
- GNB1L | c.437C>T p.P146L | Missense Mutation (SNP) | VAF 530/808 reads (66%) | SIFT deleterious (0.01); PolyPhen benign (0.132); catalogued as rs1305538230; called by muse, mutect2, varscan2
- GOLGA8O | c.456G>A p.M152I | Missense Mutation (SNP) | VAF 171/414 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.039); catalogued as rs1056598582; called by muse, mutect2, varscan2
- GOLGA8T | c.638C>T p.S213F | Missense Mutation (SNP) | VAF 318/761 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.625); catalogued as rs769273676; called by muse, mutect2, varscan2
- GOLGB1 | c.5506A>G p.N1836D | Missense Mutation (SNP) | VAF 62/109 reads (57%) | SIFT tolerated (0.14); PolyPhen benign (0.27); catalogued as rs750444253; called by muse, mutect2, varscan2
- GPC5 | c.250G>A p.D84N | Missense Mutation (SNP) | VAF 26/91 reads (29%) | SIFT tolerated (0.34); PolyPhen benign (0.326); catalogued as COSV65573553; called by muse, mutect2, varscan2
- GPR149 | c.170C>T p.S57F | Missense Mutation (SNP) | VAF 134/320 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); catalogued as rs1232531439; called by muse, mutect2, varscan2
- GPR153 | c.1772C>T p.P591L | Missense Mutation (SNP) | VAF 29/221 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.026); catalogued as rs762920453; called by muse, mutect2, varscan2
- GPR156 | c.629C>T p.S210L | Missense Mutation (SNP) | VAF 35/215 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs761380158; called by muse, mutect2, varscan2
- GPR158 | c.1882C>T p.H628Y | Missense Mutation (SNP) | VAF 28/55 reads (51%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.791); catalogued as COSV100893693; called by muse, mutect2, varscan2
- GPR179 | c.3790G>A p.E1264K (on ENST00000621958; = p.E1263K on NM_001004334.4) | Missense Mutation (SNP) | VAF 141/346 reads (41%) | SIFT tolerated (0.22); PolyPhen benign (0.063); catalogued as rs376112804; called by muse, mutect2, varscan2
- GPR87 | c.1048C>T p.R350C | Missense Mutation (SNP) | VAF 16/33 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs1331356491, COSV53462851, COSV53462905; called by muse, mutect2
- GPRC6A | c.2695C>T p.Q899* | Nonsense Mutation (SNP) | VAF 103/122 reads (84%) | catalogued as rs750148259; called by muse, mutect2, varscan2
- GRB7 | c.1212G>A p.K404= | Splice Region (SNP) | VAF 126/559 reads (23%) | catalogued as COSV58447368; called by muse, mutect2, varscan2
- GRIK3 | c.1802C>T p.S601F | Missense Mutation (SNP) | VAF 133/452 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); catalogued as COSV66138266; called by muse, mutect2, varscan2
- GRIP1 | c.346G>A p.E116K | Missense Mutation (SNP) | VAF 46/183 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54025633; called by muse, mutect2, varscan2
- GRIP2 | c.121C>T p.P41S | Missense Mutation (SNP) | VAF 334/743 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.009); catalogued as rs969986001; called by muse, mutect2, varscan2
- GRM3 | c.580G>A p.D194N | Missense Mutation (SNP) | VAF 88/210 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100862005; called by muse, varscan2
- GRM5 | c.2630+1G>A p.X877_splice | Splice Site (SNP) | VAF 17/31 reads (55%) | catalogued as COSV59605560; called by muse, mutect2, varscan2
- GRM5 | c.2492G>A p.R831K | Missense Mutation (SNP) | VAF 59/185 reads (32%) | SIFT tolerated (0.44); PolyPhen benign (0.01); catalogued as rs1185114477; called by muse, mutect2, varscan2
- GRM7 | c.517C>T p.Q173* | Nonsense Mutation (SNP) | VAF 44/79 reads (56%) | catalogued as COSV63142433; called by muse, mutect2, varscan2
- GTF2H2 | c.751C>T p.R251C | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as COSV99174111; called by muse, mutect2, varscan2
- GXYLT1 | c.1294C>T p.R432C | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.513); catalogued as rs75740340, COSV99789204; called by muse, mutect2, varscan2
- HAP1 | c.1384C>T p.P462S | Missense Mutation (SNP) | VAF 282/475 reads (59%) | SIFT tolerated (0.33); PolyPhen benign (0.001); catalogued as rs1260313399; called by muse, mutect2, varscan2
- HBB | c.67G>A p.E23K | Missense Mutation (SNP) | VAF 90/260 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.092); catalogued as rs33959855, CD083310, CM057105, CM073121, CM920319, COSV58943203; ClinVar: uncertain significance / other; called by muse, mutect2, varscan2
- HCAR3 | c.188G>A p.R63Q | Missense Mutation (SNP) | VAF 108/386 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.853); catalogued as rs576709985, COSV63675799; called by muse, mutect2, varscan2
- HCLS1 | c.640G>A p.E214K | Missense Mutation (SNP) | VAF 141/335 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.511); catalogued as COSV58854648, COSV58860531; called by muse, mutect2, varscan2
- HDC | c.188G>A p.R63Q | Missense Mutation (SNP) | VAF 240/566 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0.028); catalogued as rs769839707, COSV51068917; called by muse, mutect2, varscan2
- HDGFL1 | c.265C>T p.Q89* | Nonsense Mutation (SNP) | VAF 182/300 reads (61%) | catalogued as COSV57752718, COSV57753391; called by muse, mutect2, varscan2
- HEATR5B | c.3073C>T p.R1025C | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs267599367, COSV51848925; called by muse, mutect2, varscan2
- HEATR6 | c.1976C>T p.S659F | Missense Mutation (SNP) | VAF 42/234 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.687); catalogued as COSV51745807; called by muse, mutect2, varscan2
- HECTD4 | c.13138C>T p.R4380C | Missense Mutation (SNP) | VAF 88/158 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as rs1566055535, COSV66386466; called by muse, mutect2, varscan2
- HEPHL1 | c.1005G>A p.M335I | Missense Mutation (SNP) | VAF 59/154 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1207012361; called by muse, mutect2, varscan2
- HEPHL1 | c.2858G>A p.R953Q | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs939355851, COSV59889696; called by muse, mutect2, varscan2
- HEXIM2 | c.262C>T p.R88W | Missense Mutation (SNP) | VAF 200/426 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs201451805, COSV100218015; called by muse, mutect2, varscan2
- HGF | c.1064G>A p.R355Q | Missense Mutation (SNP) | VAF 49/104 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55948411; called by muse, mutect2, varscan2
- HHLA1 | c.581G>A p.G194E | Missense Mutation (SNP) | VAF 43/71 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs867856926; called by muse, mutect2, varscan2
- HHLA2 | c.516G>A p.W172* | Nonsense Mutation (SNP) | VAF 56/182 reads (31%) | catalogued as rs1272904239, COSV63320800; called by muse, mutect2, varscan2
- HIF3A | c.1291C>T p.P431S (on ENST00000377670 / NM_152795.4; = p.P362S on NM_022462.4) | Missense Mutation (SNP) | VAF 82/177 reads (46%) | SIFT tolerated (0.11); PolyPhen benign (0.063); catalogued as COSV99355957; called by muse, mutect2, varscan2
- HIPK3 | c.451C>G p.P151A | Missense Mutation (SNP) | VAF 28/83 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.348); catalogued as rs779796961; called by muse, mutect2, varscan2
- HIRA | c.2324C>T p.S775F | Missense Mutation (SNP) | VAF 389/599 reads (65%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as rs1556012778, COSV99600179; called by muse, mutect2, varscan2
- HK3 | c.1348G>A p.E450K | Missense Mutation (SNP) | VAF 52/170 reads (31%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as COSV99034787; called by muse, mutect2, varscan2
- HLA-DRA | c.317C>T p.P106L | Missense Mutation (SNP) | VAF 71/123 reads (58%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.865); catalogued as rs754838655, COSV66622479; called by muse, mutect2, varscan2
- HMGCL | c.20C>T p.A7V | Missense Mutation (SNP) | VAF 141/1221 reads (12%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0); catalogued as rs754437215; called by muse, mutect2, varscan2
- HMGCL | c.19G>T p.A7S | Missense Mutation (SNP) | VAF 140/1226 reads (11%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as COSV99030282; called by muse, mutect2, varscan2
- HMGCS1 | c.1321C>T p.P441S | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV57289917; called by muse, varscan2
- HNRNPCL2 | c.307G>A p.E103K | Missense Mutation (SNP) | VAF 223/876 reads (25%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.468); catalogued as rs776662820; called by muse, mutect2, varscan2
- HOXA3 | c.997G>A p.G333R | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.241); catalogued as rs1366839347; called by muse, mutect2, varscan2
- HPN | c.721G>A p.G241R | Missense Mutation (SNP) | VAF 347/454 reads (76%) | SIFT tolerated (0.18); PolyPhen benign (0.158); catalogued as rs758071341, COSV52882538, COSV52886631; called by muse, mutect2, varscan2
- HRC | c.874G>A p.D292N | Missense Mutation (SNP) | VAF 46/110 reads (42%) | SIFT tolerated (0.32); PolyPhen benign (0.015); catalogued as rs528365011; called by muse, mutect2, varscan2
- HRH1 | c.619C>T p.L207F | Missense Mutation (SNP) | VAF 93/192 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67955939; called by muse, mutect2, varscan2
- HSPA12A | c.1390C>T p.R464W | Missense Mutation (SNP) | VAF 47/87 reads (54%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.663); catalogued as rs781927735, COSV65023418; called by muse, mutect2, varscan2
- HSPA12B | c.1142C>T p.P381L | Missense Mutation (SNP) | VAF 102/584 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs773362896; called by muse, mutect2, varscan2
- HSPG2 | c.1213C>T p.P405S | Missense Mutation (SNP) | VAF 64/206 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as rs766511202, COSV101012941; called by muse, mutect2, varscan2
- HTR1A | c.119C>T p.S40F | Missense Mutation (SNP) | VAF 148/453 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.524); catalogued as rs200597572, COSV100109050; called by muse, mutect2, varscan2
- HTR2C | c.631G>A p.D211N | Missense Mutation (SNP) | VAF 78/82 reads (95%) | SIFT tolerated (0.16); PolyPhen benign (0.303); catalogued as COSV52208285; called by muse, mutect2, varscan2
- HTR2C | c.866G>A p.R289K | Missense Mutation (SNP) | VAF 146/152 reads (96%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as rs782066714; called by muse, mutect2, varscan2
- IARS1 | c.1657C>T p.P553S | Missense Mutation (SNP) | VAF 67/74 reads (91%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65117236; called by muse, mutect2, varscan2
- IDH3B | c.143C>T p.S48F | Missense Mutation (SNP) | VAF 202/479 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs1318009865, COSV66484090; called by muse, mutect2, varscan2
- IFT81 | c.1058G>A p.R353H | Missense Mutation (SNP) | VAF 53/79 reads (67%) | SIFT tolerated (0.23); PolyPhen benign (0.03); catalogued as rs765241061, COSV54365872; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IGF2R | c.2596C>T p.L866F | Missense Mutation (SNP) | VAF 65/153 reads (42%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.875); catalogued as COSV100808124; called by muse, varscan2
- IGHV1OR21-1 | c.41C>T p.A14V | Missense Mutation (SNP) | VAF 72/422 reads (17%) | SIFT tolerated (0.18); PolyPhen benign (0.085); catalogued as rs758490332; called by muse, varscan2
- IGKV2D-26 | c.119C>T p.S40F | Missense Mutation (SNP) | VAF 33/201 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.232); catalogued as rs1380751049; called by muse, mutect2, varscan2
- IGLV1-50 | c.119C>T p.S40F | Missense Mutation (SNP) | VAF 162/286 reads (57%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.229); catalogued as rs1458335208; called by muse, mutect2, varscan2
- IGSF21 | c.1234C>T p.R412C | Missense Mutation (SNP) | VAF 154/332 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1474340067, COSV52132771; called by muse, mutect2, varscan2
- IGSF9 | c.1880C>T p.P627L (on ENST00000368094 / NM_001135050.2; = p.P611L on NM_020789.4) | Missense Mutation (SNP) | VAF 27/45 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63638970; called by muse, mutect2, varscan2
- IGSF9B | c.4285G>A p.D1429N | Missense Mutation (SNP) | VAF 53/128 reads (41%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.801); catalogued as rs1243790143; called by muse, mutect2, varscan2
- IL15 | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.752); catalogued as COSV56726750; called by muse, mutect2, varscan2
- IL16 | c.3761C>T p.S1254F (on ENST00000302987 / NM_172217.5; = p.S553F on NM_004513.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 195/506 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57154019; called by muse, mutect2, varscan2
- IL18RAP | c.121G>A p.E41K | Missense Mutation (SNP) | VAF 62/99 reads (63%) | SIFT tolerated (0.18); PolyPhen benign (0.013); catalogued as COSV51824565; called by muse, varscan2
- IL37 | c.643G>A p.E215K | Missense Mutation (SNP) | VAF 48/83 reads (58%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.677); catalogued as COSV54491772; called by muse, mutect2, varscan2
- IL6 | c.422G>A p.R141K | Missense Mutation (SNP) | VAF 53/158 reads (34%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as rs751859032; called by muse, mutect2, varscan2
- IL7R | c.985C>T p.P329S | Missense Mutation (SNP) | VAF 170/288 reads (59%) | SIFT tolerated (0.35); PolyPhen benign (0.121); catalogued as COSV57407706; called by muse, mutect2, varscan2
- INSYN2B | c.299C>T p.S100F | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56957209; called by muse, mutect2, varscan2
- IQCA1 | c.376G>A p.E126K | Missense Mutation (SNP) | VAF 29/52 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs371274124; called by muse, mutect2, varscan2
- IQCC | c.187-1G>A p.X63_splice | Splice Site (SNP) | VAF 145/297 reads (49%) | catalogued as rs867660301, COSV52208567; called by muse, mutect2, varscan2
- ISLR | c.1133C>T p.P378L | Missense Mutation (SNP) | VAF 86/184 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); catalogued as COSV51434847; called by mutect2, varscan2
- ITGA4 | c.886G>A p.E296K | Missense Mutation (SNP) | VAF 14/25 reads (56%) | SIFT deleterious (0.03); PolyPhen benign (0.408); catalogued as COSV99276153; called by muse, mutect2, varscan2
- ITIH5 | c.1940C>T p.P647L | Missense Mutation (SNP) | VAF 39/75 reads (52%) | SIFT tolerated (0.25); PolyPhen benign (0.022); catalogued as rs757481104, COSV53672073; called by muse, mutect2, varscan2
- ITPR3 | c.2368C>T p.P790S | Missense Mutation (SNP) | VAF 333/701 reads (48%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.999); catalogued as rs746216904; called by muse, mutect2, varscan2
- IZUMO3 | c.268G>T p.E90* | Nonsense Mutation (SNP) | VAF 32/41 reads (78%) | catalogued as rs752844756; called by muse, mutect2, varscan2
- IZUMO4 | c.575C>T p.S192F | Missense Mutation (SNP) | VAF 93/258 reads (36%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.138); catalogued as rs1163734633; called by muse, mutect2, varscan2
- JAK3 | c.3234G>A p.W1078* | Nonsense Mutation (SNP) | VAF 113/184 reads (61%) | catalogued as COSV71685944; called by muse, mutect2, varscan2
- JARID2 | c.1462G>A p.E488K | Missense Mutation (SNP) | VAF 105/240 reads (44%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.681); catalogued as rs1345467460; called by muse, mutect2, varscan2
- KALRN | c.3962G>A p.G1321E | Missense Mutation (SNP) | VAF 71/145 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1451637199; called by muse, mutect2, varscan2
- KALRN | c.4462T>G p.S1488A | Missense Mutation (SNP) | VAF 124/304 reads (41%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.966); catalogued as COSV53769100; called by muse, mutect2, varscan2
- KALRN | c.7126G>A p.V2376I (on ENST00000360013 / NM_001024660.4; = p.V679I on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 49/108 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV52265964; called by muse, mutect2, varscan2
- KALRN | c.8761G>A p.E2921K (on ENST00000360013 / NM_001024660.4; = p.E1224K on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 180/403 reads (45%) | SIFT tolerated (0.76); PolyPhen benign (0.339); catalogued as rs184120997, COSV52262662; called by muse, mutect2, varscan2
- KANK2 | c.2410C>T p.R804C (on ENST00000586659 / NM_001379562.1; = p.R812C on NM_015493.7 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 66/264 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); catalogued as rs762959202; called by muse, mutect2, varscan2
- KANSL1L | c.2162G>A p.R721K | Missense Mutation (SNP) | VAF 26/30 reads (87%) | SIFT tolerated (0.28); PolyPhen benign (0.009); catalogued as COSV55990463; called by muse, mutect2, varscan2
- KAT6A | c.3256C>T p.R1086C | Missense Mutation (SNP) | VAF 34/140 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs61753683; called by muse, mutect2, varscan2
- KCNA3 | c.379G>A p.E127K | Missense Mutation (SNP) | VAF 227/250 reads (91%) | SIFT tolerated (0.06); PolyPhen benign (0.155); catalogued as COSV63902597; called by muse, mutect2, varscan2
- KCNA6 | c.1201G>A p.D401N | Missense Mutation (SNP) | VAF 108/427 reads (25%) | SIFT tolerated (0.28); PolyPhen benign (0.039); catalogued as COSV54977698; called by muse, mutect2, varscan2
- KCNB2 | c.139G>A p.E47K | Missense Mutation (SNP) | VAF 38/73 reads (52%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.934); catalogued as rs866484467, COSV73051743; called by muse, mutect2, varscan2
- KCNC4 | c.491C>T p.P164L | Missense Mutation (SNP) | VAF 231/353 reads (65%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as COSV63926801; called by muse, mutect2, varscan2
- KCNH4 | c.2447G>A p.G816E | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.58); PolyPhen benign (0.236); catalogued as COSV52919117; called by muse, mutect2, varscan2
- KCNQ2 | c.2570C>T p.T857I (on ENST00000359125 / NM_172107.4; = p.T829I on NM_004518.6) | Missense Mutation (SNP) | VAF 65/301 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs753368036; called by muse, mutect2, varscan2
- KCNQ3 | c.888G>A p.M296I | Missense Mutation (SNP) | VAF 101/370 reads (27%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as rs1172039592, COSV101196291; called by muse, mutect2, varscan2
- KCNT2 | c.958G>A p.E320K | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54074924; called by muse, mutect2, varscan2
- KERA | c.679G>A p.G227R | Missense Mutation (SNP) | VAF 31/97 reads (32%) | SIFT tolerated (0.42); PolyPhen benign (0.009); catalogued as rs150036305, COSV99899329; called by muse, mutect2, varscan2
- KIAA1109 | c.14044C>T p.H4682Y | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as COSV52696198, COSV99153869; called by muse, mutect2, varscan2
- KIAA1210 | c.4411G>A p.D1471N | Missense Mutation (SNP) | VAF 68/76 reads (89%) | SIFT tolerated (0.12); PolyPhen benign (0.318); catalogued as COSV68177254, COSV68177446; called by muse, mutect2, varscan2
- KIAA1549 | c.1184G>A p.S395N | Missense Mutation (SNP) | VAF 77/160 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.015); catalogued as COSV54327077; called by muse, mutect2, varscan2
- KIAA1671 | c.127C>T p.P43S | Missense Mutation (SNP) | VAF 101/185 reads (55%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.61); catalogued as rs955866452; called by muse, mutect2, varscan2
- KIF21A | c.2176C>T p.Q726* (on ENST00000361418 / NM_001378440.1; = p.Q713* on NM_017641.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 23/84 reads (27%) | catalogued as COSV62771594; called by muse, mutect2, varscan2
- KIF26A | c.2188G>A p.A730T | Missense Mutation (SNP) | VAF 69/135 reads (51%) | SIFT tolerated (0.75); PolyPhen benign (0.014); catalogued as COSV100181465; called by muse, mutect2, varscan2
- KIF26A | c.5377G>A p.E1793K | Missense Mutation (SNP) | VAF 100/262 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); catalogued as COSV59469824; called by muse, mutect2, varscan2
- KIRREL2 | c.2068C>T p.P690S | Missense Mutation (SNP) | VAF 96/182 reads (53%) | SIFT tolerated (0.45); PolyPhen benign (0.326); catalogued as rs769239424, COSV52878031; called by muse, mutect2, varscan2
- KISS1 | c.353G>A p.G118D | Missense Mutation (SNP) | VAF 119/416 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV65817049; called by muse, varscan2
- KLC2 | c.1088C>T p.P363L | Missense Mutation (SNP) | VAF 42/110 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.681); catalogued as rs868367442, COSV57582438; called by muse, mutect2, varscan2
- KLHDC7A | c.1837G>A p.D613N | Missense Mutation (SNP) | VAF 138/419 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.348); catalogued as rs868230243, COSV101272770; called by muse, mutect2, varscan2
- KLHDC8A | c.782C>T p.S261L | Missense Mutation (SNP) | VAF 66/197 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.234); catalogued as rs766875332, COSV65679013, COSV65679062; called by muse, mutect2, varscan2
- KLK8 | c.487C>T p.P163S | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT tolerated (0.11); PolyPhen benign (0.329); catalogued as rs1332741543, COSV51594392; called by muse, mutect2, varscan2
- KLK9 | c.237G>A p.W79* | Nonsense Mutation (SNP) | VAF 24/47 reads (51%) | catalogued as COSV51591560; called by muse, mutect2, varscan2
- KLLN | c.358C>T p.P120S | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.7); catalogued as rs1398508098; called by muse, mutect2, varscan2
- KLRK1 | c.191G>A p.G64E | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); catalogued as rs753001440, COSV53698178; called by muse, mutect2, varscan2
- KMT2D | c.8546C>T p.A2849V | Missense Mutation (SNP) | VAF 66/236 reads (28%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as rs370940954; called by muse, mutect2, varscan2
- KRT2 | c.308G>A p.G103E | Missense Mutation (SNP) | VAF 50/141 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.123); catalogued as rs779761041; called by muse, mutect2, varscan2
- KRT32 | c.77C>T p.S26F | Missense Mutation (SNP) | VAF 214/448 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.028); catalogued as rs1231598018, COSV56785790; called by muse, mutect2, varscan2
- KRT40 | c.531-1G>A p.X177_splice | Splice Site (SNP) | VAF 19/49 reads (39%) | catalogued as rs1213920368; called by muse, mutect2
- KRT73 | c.1156G>A p.D386N | Missense Mutation (SNP) | VAF 72/248 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.639); catalogued as rs761352447; called by muse, mutect2, varscan2
- KRT79 | c.919C>T p.R307C | Missense Mutation (SNP) | VAF 55/269 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as rs773888485, COSV100398328; called by muse, mutect2, varscan2
- KRT86 | c.984G>A p.M328I | Missense Mutation (SNP) | VAF 172/1118 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs752211932, COSV53291952; called by muse, mutect2
- KRT9 | c.1306G>A p.E436K | Missense Mutation (SNP) | VAF 452/759 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs1241387766, COSV55853262; called by muse, mutect2, varscan2
- KRTAP11-1 | c.224C>T p.S75L | Missense Mutation (SNP) | VAF 134/238 reads (56%) | SIFT tolerated (0.12); PolyPhen benign (0.419); catalogued as rs1568960223; called by muse, mutect2, varscan2
- L34079.1 | c.17T>C p.L6P | Missense Mutation (SNP) | VAF 153/194 reads (79%) | catalogued as rs949148377; called by muse, mutect2, varscan2
- LAMA2 | c.3728G>A p.G1243E | Missense Mutation (SNP) | VAF 102/122 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs368726141; called by muse, mutect2, varscan2
- LAMA3 | c.589G>A p.E197K | Missense Mutation (SNP) | VAF 94/151 reads (62%) | SIFT tolerated (0.13); PolyPhen benign (0.039); catalogued as COSV58063947, COSV58067084; called by muse, mutect2, varscan2
- LAMA5 | c.10169C>T p.P3390L | Missense Mutation (SNP) | VAF 53/265 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.057); catalogued as rs772171641; called by muse, mutect2, varscan2
- LAMA5 | c.5563G>A p.G1855S | Missense Mutation (SNP) | VAF 165/379 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); catalogued as rs1170849958, COSV99442742; called by muse, mutect2, varscan2
- LAMB4 | c.3343G>A p.E1115K | Missense Mutation (SNP) | VAF 44/132 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs759129903; called by muse, varscan2
- LCMT1 | c.884+1G>A p.X295_splice | Splice Site (SNP) | VAF 30/32 reads (94%) | catalogued as COSV66727035; called by muse, mutect2, varscan2
- LCN1 | c.478G>A p.E160K | Missense Mutation (SNP) | VAF 38/102 reads (37%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.979); catalogued as rs1186047541; called by muse, mutect2, varscan2
- LEMD2 | c.1102C>T p.R368C | Missense Mutation (SNP) | VAF 53/128 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs146180267; called by muse, mutect2, varscan2
- LHCGR | c.309-1G>A p.X103_splice | Splice Site (SNP) | VAF 100/179 reads (56%) | catalogued as COSV54296823; called by muse, mutect2, varscan2
- LILRB3 | c.550G>A p.G184S | Missense Mutation (SNP) | VAF 92/844 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.811); catalogued as rs774104467; called by muse, varscan2
- LOXHD1 | c.4481G>A p.R1494Q | Missense Mutation (SNP) | VAF 36/167 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); catalogued as rs949457669; called by muse, mutect2, varscan2
- LOXHD1 | c.91G>A p.D31N | Missense Mutation (SNP) | VAF 68/227 reads (30%) | SIFT tolerated (0.63); PolyPhen benign (0.003); catalogued as rs876657862; called by muse, mutect2, varscan2
- LPA | c.5180G>T p.G1727V | Missense Mutation (SNP) | VAF 169/204 reads (83%) | SIFT deleterious (0.02); PolyPhen benign (0.141); catalogued as COSV60300607; called by muse, mutect2, varscan2
- LRFN2 | c.1739A>G p.N580S | Missense Mutation (SNP) | VAF 111/232 reads (48%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs764108679; called by muse, mutect2, varscan2
- LRP1B | c.13450G>A p.G4484R | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67221305; called by muse, mutect2, varscan2
- LRP1B | c.8545G>A p.E2849K | Missense Mutation (SNP) | VAF 21/28 reads (75%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.914); catalogued as COSV101249249, COSV67269323; called by muse, mutect2, varscan2
- LRP1B | c.7907T>C p.L2636P | Missense Mutation (SNP) | VAF 34/41 reads (83%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); catalogued as rs150122153; called by muse, mutect2, varscan2
- LRP1B | c.3769C>T p.P1257S | Missense Mutation (SNP) | VAF 8/8 reads (100%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV67197601; called by muse, mutect2
- LRP1B | c.1996G>A p.E666K | Missense Mutation (SNP) | VAF 90/155 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV67218154, COSV67218439; called by muse, mutect2, varscan2
- LRP6 | c.2702C>T p.S901F | Missense Mutation (SNP) | VAF 82/255 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.783); catalogued as rs1036036352, COSV53789024; called by muse, mutect2, varscan2
- LRRC30 | c.808C>T p.H270Y | Missense Mutation (SNP) | VAF 124/206 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV67302459; called by muse, varscan2
- LRRC4C | c.346G>A p.E116K | Missense Mutation (SNP) | VAF 39/100 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV53434224; called by muse, mutect2, varscan2
- LRRC8B | c.920C>T p.S307F | Missense Mutation (SNP) | VAF 41/166 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.737); catalogued as COSV58376038; called by muse, mutect2, varscan2
- LRRIQ3 | c.739G>A p.E247K | Missense Mutation (SNP) | VAF 21/27 reads (78%) | SIFT tolerated (0.42); PolyPhen benign (0.005); catalogued as rs1296939696, COSV100598566, COSV63048593; called by muse, mutect2, varscan2
- LRRN1 | c.1300C>T p.R434C | Missense Mutation (SNP) | VAF 43/92 reads (47%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.533); catalogued as rs1300200167, COSV60012895; called by muse, mutect2, varscan2
- LRRTM1 | c.1240C>T p.P414S | Missense Mutation (SNP) | VAF 131/196 reads (67%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as rs780995966; called by muse, mutect2, varscan2
- LRTM1 | c.679G>T p.E227* | Nonsense Mutation (SNP) | VAF 49/107 reads (46%) | catalogued as rs1559628939; called by muse, mutect2, varscan2
- LRTM1 | c.260C>T p.S87L | Missense Mutation (SNP) | VAF 35/74 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.233); catalogued as rs866923787; called by muse, mutect2, varscan2
- LTBP2 | c.4851G>A p.W1617* | Nonsense Mutation (SNP) | VAF 195/391 reads (50%) | catalogued as COSV56211672; called by muse, mutect2, varscan2
- LTF | c.1891G>A p.V631M | Missense Mutation (SNP) | VAF 74/169 reads (44%) | SIFT tolerated (0.28); PolyPhen benign (0.406); catalogued as rs1280155518; called by muse, mutect2
- LUZP2 | c.457G>A p.E153K | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs776145449; called by muse, mutect2, varscan2
- LUZP4 | c.488G>A p.R163Q | Missense Mutation (SNP) | VAF 92/98 reads (94%) | SIFT tolerated (0.16); PolyPhen benign (0.009); catalogued as rs782529754; called by muse, mutect2, varscan2
- LY9 | c.1793G>A p.G598E | Missense Mutation (SNP) | VAF 31/122 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV54439142; called by muse, mutect2
- MACF1 | c.12196C>T p.R4066C (on ENST00000372915; = p.R1999C on NM_012090.5) | Missense Mutation (SNP) | VAF 40/394 reads (10%) | catalogued as rs201462187, COSV57107007, COSV57124998; called by muse, mutect2
- MACROD2 | c.1066G>A p.D356N (on ENST00000642719; = p.D328N on NM_080676.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 35/74 reads (47%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as rs751370265, COSV53977195; called by muse, mutect2, varscan2
- MACROH2A2 | c.200C>T p.A67V | Missense Mutation (SNP) | VAF 73/162 reads (45%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs868217028; called by muse, mutect2, varscan2
- MAGEB6B | c.359C>T p.S120L | Missense Mutation (SNP) | VAF 142/171 reads (83%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV69689602; called by muse, mutect2, varscan2
- MAGEC1 | c.367G>A p.D123N | Missense Mutation (SNP) | VAF 113/119 reads (95%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.539); catalogued as COSV53572619; called by muse, mutect2, varscan2
- MAGEC2 | c.751G>A p.E251K | Missense Mutation (SNP) | VAF 105/117 reads (90%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.627); catalogued as COSV55998298; called by muse, mutect2, varscan2
- MAGEL2 | c.1825G>A p.V609M | Missense Mutation (SNP) | VAF 235/538 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.222); catalogued as rs1400051343; called by muse, mutect2, varscan2
- MAGI2 | c.1531C>T p.P511S | Missense Mutation (SNP) | VAF 71/183 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as COSV62640708; called by muse, mutect2, varscan2
- MAP4 | c.1957C>T p.P653S | Missense Mutation (SNP) | VAF 92/214 reads (43%) | SIFT tolerated (0.05); PolyPhen benign (0.293); catalogued as COSV53143554; called by muse, mutect2, varscan2
- MAP6 | c.1315G>A p.E439K | Missense Mutation (SNP) | VAF 55/121 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV59076615; called by muse, mutect2, varscan2
- MARCHF1 | c.423G>A p.K141= (on ENST00000274056; = p.K124= on NM_017923.4) | Splice Region (SNP) | VAF 29/52 reads (56%) | catalogued as COSV99922627; called by muse, mutect2, varscan2
- MARCHF2 | c.508C>T p.H170Y | Missense Mutation (SNP) | VAF 175/1494 reads (12%) | SIFT tolerated (0.52); PolyPhen benign (0.185); catalogued as COSV53107145; called by muse, mutect2, varscan2
- MATN4 | c.557C>T p.S186L | Missense Mutation (SNP) | VAF 24/69 reads (35%) | PolyPhen probably damaging (0.999); catalogued as rs939059210, COSV59213375; called by muse, mutect2, varscan2
- MC2R | c.539C>T p.S180L | Missense Mutation (SNP) | VAF 144/221 reads (65%) | SIFT deleterious (0.01); PolyPhen benign (0.081); catalogued as rs1450506072, CM057717, COSV59617321; called by muse, mutect2, varscan2
- MCCC1 | c.1222C>T p.P408S | Missense Mutation (SNP) | VAF 105/240 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); catalogued as rs1560224165; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MCM2 | c.2468C>T p.S823L | Missense Mutation (SNP) | VAF 52/189 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.027); catalogued as COSV54031871, COSV54037920; called by muse, varscan2
- MDC1 | c.4370C>T p.P1457L | Missense Mutation (SNP) | VAF 21/87 reads (24%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.993); catalogued as rs1345109386; called by muse, mutect2, varscan2
- MDGA1 | c.2203C>G p.R735G | Missense Mutation (SNP) | VAF 18/31 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99776500; called by muse, mutect2, varscan2
- MDGA2 | c.2945C>T p.S982L (on ENST00000399232 / NM_001113498.2; = p.S684L on NM_182830.4) | Missense Mutation (SNP) | VAF 50/122 reads (41%) | SIFT tolerated (0.25); PolyPhen benign (0.132); catalogued as COSV62119807; called by muse, mutect2, varscan2
- MED13L | c.3973C>T p.R1325C | Missense Mutation (SNP) | VAF 157/260 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs374881943; called by muse, mutect2, varscan2
- MEF2C | c.1289C>T p.S430L | Missense Mutation (SNP) | VAF 241/430 reads (56%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as COSV60926568; called by muse, mutect2, varscan2
- MEGF6 | c.956C>T p.A319V | Missense Mutation (SNP) | VAF 436/636 reads (69%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.583); catalogued as COSV53889596; called by muse, mutect2, varscan2
- MEN1 | c.1673T>A p.F558Y | Missense Mutation (SNP) | VAF 167/350 reads (48%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.816); catalogued as CD983973; called by muse, mutect2, varscan2
- MFAP3 | c.391C>T p.R131C | Missense Mutation (SNP) | VAF 98/165 reads (59%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.545); catalogued as rs770333252, COSV59455545; called by muse, mutect2, varscan2
- MGAM | c.652G>A p.E218K | Missense Mutation (SNP) | VAF 45/117 reads (38%) | SIFT tolerated (0.19); PolyPhen benign (0.011); catalogued as rs202247797, COSV71885480; called by muse, mutect2, varscan2
- MGAM | c.4610C>T p.S1537F | Missense Mutation (SNP) | VAF 129/263 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101527718, COSV72076134; called by muse, mutect2, varscan2
- MGAM | c.5398G>A p.E1800K | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs267601328, COSV72073671; called by muse, mutect2, varscan2
- MGAM2 | c.4217C>T p.S1406F | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.959); catalogued as rs1478519818; called by muse, mutect2, varscan2
- MGLL | c.352C>T p.L118F (on ENST00000398104 / NM_001003794.2; = p.L128F on NM_007283.6) | Missense Mutation (SNP) | VAF 297/682 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as rs773791349; called by muse, mutect2, varscan2
- MICAL3 | c.4535C>T p.S1512L | Missense Mutation (SNP) | VAF 109/407 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.537); catalogued as rs767739579, COSV71588854; called by muse, mutect2, varscan2
- MICU3 | c.196G>A p.E66K | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated, low confidence (0.14); PolyPhen possibly damaging (0.899); catalogued as rs905070817, COSV100536353; called by muse, mutect2, varscan2
- MINAR1 | c.1347T>A p.H449Q | Missense Mutation (SNP) | VAF 78/159 reads (49%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as rs201473692; called by muse, mutect2, varscan2
- MLIP | c.202C>T p.P68S | Missense Mutation (SNP) | VAF 73/120 reads (61%) | SIFT tolerated (0.17); PolyPhen benign (0.055); catalogued as COSV51425953; called by muse, mutect2, varscan2
- MLIP | c.458G>A p.G153E | Missense Mutation (SNP) | VAF 52/168 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); catalogued as COSV51428624; called by muse, varscan2
- MLIP | c.541G>A p.G181R | Missense Mutation (SNP) | VAF 53/87 reads (61%) | SIFT deleterious (0.04); PolyPhen benign (0.325); catalogued as COSV51428217; called by muse, varscan2
- MMAB | c.146C>T p.S49F | Missense Mutation (SNP) | VAF 192/332 reads (58%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.687); catalogued as COSV57170288; called by muse, mutect2, varscan2
- MMD2 | c.758C>T p.A253V (on ENST00000404774 / NM_001100600.2; = p.A229V on NM_198403.4) | Missense Mutation (SNP) | VAF 97/259 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1362205044, COSV68659768; called by muse, mutect2, varscan2
- MME | c.1873C>T p.Q625* | Nonsense Mutation (SNP) | VAF 115/299 reads (38%) | catalogued as COSV64706102; called by muse, mutect2, varscan2
- MMP1 | c.536G>A p.G179E | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.856); catalogued as COSV59510428; called by muse, mutect2, varscan2
- MMP13 | c.134C>T p.S45L | Missense Mutation (SNP) | VAF 94/227 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.014); catalogued as COSV52823367; called by muse, mutect2, varscan2
- MMRN2 | c.1678G>A p.A560T | Missense Mutation (SNP) | VAF 80/173 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.024); catalogued as rs1453809344; called by muse, mutect2, varscan2
- MN1 | c.3379C>T p.P1127S | Missense Mutation (SNP) | VAF 74/233 reads (32%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.896); catalogued as COSV56561896; called by muse, varscan2
- MN1 | c.3307C>T p.L1103F | Missense Mutation (SNP) | VAF 34/235 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs1568983595; called by muse, varscan2
- MN1 | c.3172G>A p.E1058K | Missense Mutation (SNP) | VAF 107/313 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.839); catalogued as COSV56560868; called by muse, mutect2, varscan2
- MOCS1 | c.1175C>T p.S392F | Missense Mutation (SNP) | VAF 28/116 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.01); catalogued as rs1404897954, COSV51305242; called by muse, mutect2, varscan2
- MORC1 | c.337G>A p.D113N | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV51713750; called by muse, mutect2, varscan2
- MOV10L1 | c.641G>A p.G214E | Missense Mutation (SNP) | VAF 425/446 reads (95%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.674); catalogued as rs761424601; called by muse, mutect2, varscan2
- MPC2 | c.337C>T p.R113C | Missense Mutation (SNP) | VAF 58/96 reads (60%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as rs17343090, COSV54797345; called by muse, varscan2
- MPP4 | c.1408G>A p.E470K | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as rs772583255, COSV59628629; called by muse, varscan2
- MREG | c.589C>T p.P197S | Missense Mutation (SNP) | VAF 35/71 reads (49%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.275); catalogued as rs759891263; called by muse, mutect2, varscan2
- MROH2B | c.2704G>A p.E902K | Missense Mutation (SNP) | VAF 35/122 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.254); catalogued as rs1035848918, COSV101270871, COSV68181875; called by muse, mutect2, varscan2
- MS4A6E | c.265G>A p.E89K | Missense Mutation (SNP) | VAF 69/153 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs752908828, COSV55726872; called by muse, mutect2, varscan2
- MSLNL | c.1382C>T p.A461V | Missense Mutation (SNP) | VAF 106/112 reads (95%) | SIFT tolerated (0.09); PolyPhen benign (0.433); catalogued as rs1424284592; called by muse, mutect2, varscan2
- MSR1 | c.724G>A p.G242R | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT tolerated (0.68); PolyPhen benign (0.006); catalogued as rs1296533085, COSV50527772; called by muse, mutect2, varscan2
- MSR1 | c.106C>T p.P36S | Missense Mutation (SNP) | VAF 61/101 reads (60%) | SIFT tolerated (0.13); PolyPhen benign (0.084); catalogued as CM023574, COSV100027633, COSV50507232; called by muse, mutect2, varscan2
- MTF1 | c.1319C>T p.P440L | Missense Mutation (SNP) | VAF 104/843 reads (12%) | SIFT tolerated (0.31); PolyPhen benign (0.003); catalogued as rs1437120753, COSV65988435; called by muse, mutect2, varscan2
- MTMR9 | c.1228C>T p.Q410* | Nonsense Mutation (SNP) | VAF 21/81 reads (26%) | catalogued as rs144892652; called by muse, mutect2, varscan2
- MTNR1A | c.239C>T p.P80L | Missense Mutation (SNP) | VAF 108/373 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as rs747255185, COSV56155162; called by muse, mutect2, varscan2
- MTO1 | c.1195C>T p.P399S | Missense Mutation (SNP) | VAF 62/108 reads (57%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0); catalogued as rs767708988; called by muse, mutect2, varscan2
- MUC16 | c.40990G>A p.E13664K | Missense Mutation (SNP) | VAF 56/285 reads (20%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.915); catalogued as COSV66691524; called by muse, mutect2, varscan2
- MUC16 | c.28394C>T p.S9465F | Missense Mutation (SNP) | VAF 35/220 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as COSV67502710; called by muse, mutect2, varscan2
- MUC16 | c.25309C>T p.L8437F | Missense Mutation (SNP) | VAF 168/220 reads (76%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.076); catalogued as rs779729631, COSV67460274, COSV67464951; called by muse, mutect2, varscan2
- MUC16 | c.23188G>A p.D7730N | Missense Mutation (SNP) | VAF 52/284 reads (18%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); catalogued as COSV67478549; called by muse, mutect2, varscan2
- MUC16 | c.8983C>T p.P2995S | Missense Mutation (SNP) | VAF 270/348 reads (78%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.932); catalogued as COSV67477601; called by muse, mutect2, varscan2
- MUC19 | c.134C>T p.S45L | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT tolerated, low confidence (0.39); PolyPhen possibly damaging (0.844); catalogued as rs1188879179; called by muse, mutect2, varscan2
- MUC4 | c.12434T>C p.L4145P | Missense Mutation (SNP) | VAF 212/1144 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.988); catalogued as rs753632233; called by muse, varscan2
- MUC4 | c.6820C>T p.P2274S | Missense Mutation (SNP) | VAF 278/2006 reads (14%) | SIFT tolerated, low confidence (0.21); PolyPhen possibly damaging (0.65); catalogued as rs1412984609, COSV62138952; called by muse, varscan2
- MUC4 | c.6143C>T p.P2048L | Missense Mutation (SNP) | VAF 283/1728 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.722); catalogued as rs781754499, COSV62164687; called by muse, mutect2, varscan2
- MUC4 | c.1556G>A p.G519E | Missense Mutation (SNP) | VAF 90/173 reads (52%) | SIFT tolerated, low confidence (0.95); PolyPhen probably damaging (0.934); catalogued as COSV62154451; called by muse, varscan2
- MUC5B | c.13148C>G p.S4383C | Missense Mutation (SNP) | VAF 164/430 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.326); catalogued as COSV101500098, COSV71591597; called by muse, mutect2, varscan2
- MUC5B | c.16246G>A p.G5416R | Missense Mutation (SNP) | VAF 54/153 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV101500638; called by muse, mutect2, varscan2
- MVB12B | c.202G>T p.V68L | Missense Mutation (SNP) | VAF 71/82 reads (87%) | SIFT tolerated (0.06); PolyPhen benign (0.028); catalogued as COSV63259497; called by muse, mutect2, varscan2
- MXRA5 | c.1399G>A p.D467N | Missense Mutation (SNP) | VAF 66/70 reads (94%) | SIFT deleterious (0.04); PolyPhen benign (0.071); catalogued as COSV99476198; called by muse, mutect2, varscan2
- MYCBPAP | c.2112G>A p.W704* | Nonsense Mutation (SNP) | VAF 76/160 reads (48%) | catalogued as COSV60408496; called by muse, varscan2
- MYF6 | c.514G>A p.E172K | Missense Mutation (SNP) | VAF 51/85 reads (60%) | SIFT tolerated (0.89); PolyPhen benign (0.006); catalogued as COSV57353222; called by muse, mutect2, varscan2
- MYH13 | c.2054C>T p.P685L | Missense Mutation (SNP) | VAF 65/100 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV99355927; called by muse, mutect2, varscan2
- MYH4 | c.4484C>T p.S1495F | Missense Mutation (SNP) | VAF 105/121 reads (87%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.595); catalogued as COSV55113531; called by muse, mutect2, varscan2
- MYH6 | c.2383C>T p.R795W | Missense Mutation (SNP) | VAF 223/520 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs202120238, COSV100676652; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYH7 | c.2575C>T p.L859F | Missense Mutation (SNP) | VAF 255/551 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.466); catalogued as rs1483811980, COSV62517580; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYO18B | c.7609G>A p.G2537S | Missense Mutation (SNP) | VAF 432/631 reads (68%) | SIFT tolerated (0.09); PolyPhen benign (0.124); catalogued as rs200890530; called by muse, mutect2, varscan2
- MYO5B | c.2310G>A p.M770I | Missense Mutation (SNP) | VAF 289/511 reads (57%) | SIFT tolerated (0.21); PolyPhen benign (0.001); catalogued as COSV53223666; called by muse, mutect2, varscan2
- N4BP2 | c.2249C>T p.S750F | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as COSV54706807; called by muse, varscan2
- N4BP2 | c.3647C>T p.S1216L | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs150403405; called by muse, mutect2, varscan2
- NAA80 | c.266C>T p.S89F (on ENST00000417393 / NM_001200018.2; = p.S111F on NM_012191.4) | Missense Mutation (SNP) | VAF 31/80 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as rs71326924, COSV56499059; called by muse, mutect2, varscan2
- NAP1L2 | c.1096C>T p.P366S | Missense Mutation (SNP) | VAF 62/72 reads (86%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.982); catalogued as rs1285007378, COSV100999227; called by muse, mutect2, varscan2
- NAV3 | c.902C>T p.S301L | Missense Mutation (SNP) | VAF 66/118 reads (56%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs775456605, COSV57078632; called by muse, mutect2
- NAV3 | c.2564G>A p.R855Q | Missense Mutation (SNP) | VAF 80/150 reads (53%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.644); catalogued as rs374085687; called by muse, mutect2, varscan2
- NCKAP5 | c.1351C>T p.P451S | Missense Mutation (SNP) | VAF 37/120 reads (31%) | SIFT tolerated (0.24); PolyPhen benign (0.022); catalogued as rs778049835, COSV58461656; called by muse, mutect2, varscan2
- NCOR2 | c.6106C>T p.R2036C | Missense Mutation (SNP) | VAF 132/200 reads (66%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs763480105; called by muse, mutect2, varscan2
- NDNF | c.1075G>A p.G359R | Missense Mutation (SNP) | VAF 42/66 reads (64%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.99); catalogued as rs868169962, COSV65632995; called by muse, mutect2, varscan2
- NDST4 | c.1210G>A p.E404K | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV52114645; called by muse, mutect2, varscan2
- NDST4 | c.34C>T p.R12* | Nonsense Mutation (SNP) | VAF 7/28 reads (25%) | catalogued as rs749271707, COSV52112958; called by muse, mutect2, varscan2
- NEB | c.11560G>A p.D3854N | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs752089716, COSV50881854, COSV51436297; called by muse, varscan2
- NEFL | c.1100G>A p.R367Q | Missense Mutation (SNP) | VAF 56/110 reads (51%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.903); catalogued as rs758969477, COSV99647794; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NELL1 | c.1874C>T p.P625L | Missense Mutation (SNP) | VAF 44/118 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.023); catalogued as rs267602822; called by muse, mutect2, varscan2
- NEUROG3 | c.145G>A p.A49T | Missense Mutation (SNP) | VAF 50/131 reads (38%) | SIFT tolerated (0.48); PolyPhen benign (0); catalogued as COSV99653508; called by muse, mutect2, varscan2
- NIM1K | c.224G>A p.R75Q | Missense Mutation (SNP) | VAF 63/115 reads (55%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.851); catalogued as rs140198619, COSV58141544; called by muse, mutect2, varscan2
- NIM1K | c.727C>T p.R243W | Missense Mutation (SNP) | VAF 154/222 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs1160102754, COSV58140727; called by muse, mutect2, varscan2
- NKPD1 | c.100C>T p.H34Y | Missense Mutation (SNP) | VAF 79/494 reads (16%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.43); catalogued as rs1272182033; called by muse, mutect2, varscan2
- NLRC4 | c.3031G>A p.D1011N | Missense Mutation (SNP) | VAF 31/45 reads (69%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.878); catalogued as COSV50873647; called by muse, mutect2, varscan2
- NLRP10 | c.1939G>A p.E647K | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV60779037; called by muse, mutect2, varscan2
- NLRP13 | c.2938C>T p.R980C | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs565649099, COSV100738195, COSV61620577; called by mutect2, varscan2
- NLRP13 | c.2593C>T p.P865S | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.074); catalogued as rs779254768; called by muse, mutect2, varscan2
- NLRP2 | c.1457G>A p.G486E | Missense Mutation (SNP) | VAF 376/513 reads (73%) | SIFT tolerated (0.14); PolyPhen benign (0.219); catalogued as rs866085205, COSV54756252; called by muse, mutect2, varscan2
- NLRP5 | c.3344C>G p.S1115C | Missense Mutation (SNP) | VAF 48/103 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); catalogued as rs369505014, COSV101173782; called by muse, mutect2, varscan2
- NLRP8 | c.2573G>A p.S858N | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT tolerated (0.31); PolyPhen benign (0.122); catalogued as COSV52582775; called by muse, mutect2, varscan2
- NME8 | c.752G>A p.R251Q | Missense Mutation (SNP) | VAF 67/141 reads (48%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs201987014, COSV52246843; called by muse, mutect2, varscan2
- NOL11 | c.1144-3C>T | Splice Region (SNP) | VAF 25/57 reads (44%) | catalogued as COSV99475226; called by muse, mutect2, varscan2
- NOS3 | c.3064C>T p.R1022W | Missense Mutation (SNP) | VAF 80/191 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs140510569; called by muse, mutect2, varscan2
- NPC1L1 | c.3638C>T p.T1213I | Missense Mutation (SNP) | VAF 173/386 reads (45%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.901); catalogued as COSV56926164; called by muse, mutect2, varscan2
- NPSR1 | c.197G>A p.G66E | Missense Mutation (SNP) | VAF 20/53 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755348662; called by muse, mutect2, varscan2
- NPY5R | c.736G>A p.E246K | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT tolerated (0.11); PolyPhen benign (0.014); catalogued as rs990663503, COSV58452444; called by muse, mutect2, varscan2
- NR1H4 | c.215C>T p.S72F (on ENST00000551379 / NM_001206993.2; = p.S62F on NM_005123.4) | Missense Mutation (SNP) | VAF 74/212 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.072); catalogued as rs868079755, COSV51849579; called by muse, varscan2
- NRAP | c.309G>A p.M103I | Missense Mutation (SNP) | VAF 35/69 reads (51%) | SIFT tolerated (0.23); PolyPhen benign (0.248); catalogued as rs1358182949; called by muse, mutect2, varscan2
- NRXN3 | c.1714G>A p.E572K (on ENST00000335750 / NM_001330195.2; = p.E199K on NM_004796.6) | Missense Mutation (SNP) | VAF 135/275 reads (49%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.987); catalogued as COSV59744823; called by muse, mutect2, varscan2
- NTF3 | c.413G>A p.R138Q | Missense Mutation (SNP) | VAF 39/154 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.212); catalogued as COSV58417648; called by muse, mutect2, varscan2
- NTN4 | c.1481C>A p.A494E | Missense Mutation (SNP) | VAF 40/197 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59221178; called by muse, mutect2, varscan2
- NTN4 | c.1317G>A p.W439* | Nonsense Mutation (SNP) | VAF 93/324 reads (29%) | catalogued as COSV100643745; called by muse, mutect2, varscan2
- NUP214 | c.5231C>T p.S1744F | Missense Mutation (SNP) | VAF 310/355 reads (87%) | SIFT deleterious (0); PolyPhen probably damaging (0.912); catalogued as COSV63910614; called by muse, mutect2, varscan2
- NXPE4 | c.220G>A p.E74K | Missense Mutation (SNP) | VAF 68/201 reads (34%) | SIFT tolerated (0.4); PolyPhen benign (0.011); catalogued as rs866741765; called by muse, mutect2, varscan2
- OBSCN | c.12616G>A p.E4206K | Missense Mutation (SNP) | VAF 149/485 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.468); catalogued as rs1202422434; called by muse, mutect2, varscan2
- OBSCN | c.13078G>A p.E4360K | Missense Mutation (SNP) | VAF 68/135 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as rs747983230, COSV52817512; called by muse, varscan2
- OBSCN | c.20122G>A p.A6708T | Missense Mutation (SNP) | VAF 39/138 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.395); catalogued as rs1387535025; called by muse, mutect2, varscan2
- OLFML2A | c.1676C>T p.S559F | Missense Mutation (SNP) | VAF 187/211 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99992468; called by muse, mutect2, varscan2
- OPHN1 | c.629C>T p.S210F | Missense Mutation (SNP) | VAF 128/134 reads (96%) | SIFT tolerated (1); PolyPhen benign (0.034); catalogued as COSV62780209; called by muse, mutect2, varscan2
- OR11G2 | c.479G>A p.R160Q | Missense Mutation (SNP) | VAF 90/214 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.337); catalogued as rs762702987, COSV62132026; called by muse, mutect2, varscan2
- OR13C2 | c.8G>A p.W3* | Nonsense Mutation (SNP) | VAF 20/25 reads (80%) | catalogued as COSV73377800; called by muse, mutect2, varscan2
- OR13G1 | c.65G>A p.G22E | Missense Mutation (SNP) | VAF 44/66 reads (67%) | SIFT tolerated (0.32); PolyPhen benign (0.045); catalogued as COSV62943525; called by muse, mutect2
- OR14I1 | c.556G>C p.V186L | Missense Mutation (SNP) | VAF 75/138 reads (54%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV61200136; called by muse, mutect2, varscan2
- OR1F1 | c.538G>A p.D180N | Missense Mutation (SNP) | VAF 134/141 reads (95%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs746066317, COSV100484439, COSV58961151; called by muse, mutect2, varscan2
- OR2A12 | c.915G>A p.W305* | Nonsense Mutation (SNP) | VAF 24/49 reads (49%) | catalogued as COSV68821065; called by muse, mutect2, varscan2
- OR2A14 | c.221C>T p.S74F | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as COSV68718074; called by muse, mutect2, varscan2
- OR2AG1 | c.586G>A p.E196K | Missense Mutation (SNP) | VAF 68/170 reads (40%) | SIFT deleterious (0.04); PolyPhen benign (0.246); catalogued as COSV56626193; called by muse, mutect2, varscan2
- OR2L8 | c.641C>T p.S214L | Missense Mutation (SNP) | VAF 38/108 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs267598488, COSV61728399; called by muse, mutect2
- OR2T10 | c.758G>A p.G253E | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs267598512; called by muse, mutect2, varscan2
- OR2T27 | c.373G>A p.A125T | Missense Mutation (SNP) | VAF 27/119 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); catalogued as rs764214284; called by mutect2, varscan2
- OR4A16 | c.272C>T p.S91F | Missense Mutation (SNP) | VAF 38/107 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.167); catalogued as rs1389734335, COSV59041785; called by muse, mutect2, varscan2
- OR4C12 | c.475C>T p.L159F | Missense Mutation (SNP) | VAF 49/105 reads (47%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.548); catalogued as COSV58859886; called by muse, mutect2, varscan2
- OR4C12 | c.248C>T p.S83F | Missense Mutation (SNP) | VAF 32/94 reads (34%) | SIFT tolerated, low confidence (0.14); PolyPhen possibly damaging (0.646); catalogued as COSV58861381; called by muse, mutect2, varscan2
- OR4E2 | c.278C>T p.S93F | Missense Mutation (SNP) | VAF 43/104 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.238); catalogued as rs866396121, COSV57731749; called by muse, mutect2, varscan2
- OR4K1 | c.149C>T p.S50F | Missense Mutation (SNP) | VAF 49/115 reads (43%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV53459293, COSV99579218; called by muse, mutect2, varscan2
- OR4K13 | c.158C>T p.S53L | Missense Mutation (SNP) | VAF 68/153 reads (44%) | SIFT tolerated (0.29); PolyPhen benign (0.02); catalogued as rs202203700, COSV59859121; called by muse, mutect2, varscan2
- OR4K5 | c.796C>T p.P266S | Missense Mutation (SNP) | VAF 76/132 reads (58%) | SIFT tolerated (0.81); PolyPhen benign (0.01); catalogued as COSV60002766, COSV60004744; called by muse, mutect2, varscan2
- OR4L1 | c.17G>A p.G6E | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV59849112, COSV59849594; called by muse, mutect2, varscan2
- OR4M1 | c.278C>T p.S93F | Missense Mutation (SNP) | VAF 113/228 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.088); catalogued as COSV60060003; called by muse, mutect2, varscan2
- OR4P4 | c.900G>A p.W300* | Nonsense Mutation (SNP) | VAF 18/18 reads (100%) | catalogued as COSV58923997; called by muse, mutect2
- OR51A2 | c.584G>A p.R195K | Missense Mutation (SNP) | VAF 32/124 reads (26%) | SIFT tolerated (0.42); PolyPhen benign (0.02); catalogued as rs267602930, COSV66748199; called by mutect2, varscan2
- OR51A4 | c.584G>A p.R195K | Missense Mutation (SNP) | VAF 45/221 reads (20%) | SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as rs267602928, COSV66749740; called by muse, mutect2, varscan2
- OR52J3 | c.583C>T p.R195C | Missense Mutation (SNP) | VAF 32/74 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as rs372164802; called by muse, mutect2, varscan2
- OR52N2 | c.277G>A p.E93K | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as rs868508493, COSV57676359; called by muse, mutect2, varscan2
- OR52R1 | c.580G>A p.D194N | Missense Mutation (SNP) | VAF 48/130 reads (37%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); catalogued as COSV100617561; called by muse, mutect2, varscan2
- OR56A4 | c.253C>T p.P85S | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.444); catalogued as rs200362281; called by muse, mutect2, varscan2
- OR56A5 | c.814C>G p.P272A | Missense Mutation (SNP) | VAF 45/84 reads (54%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.517); catalogued as COSV60827009; called by muse, mutect2, varscan2
- OR5D13 | c.337G>A p.E113K | Missense Mutation (SNP) | VAF 29/64 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as COSV62332668; called by muse, mutect2, varscan2
- OR5H15 | c.500C>T p.T167I | Missense Mutation (SNP) | VAF 42/113 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.461); catalogued as rs979568273; called by muse, mutect2, varscan2
- OR5L1 | c.811G>A p.D271N | Missense Mutation (SNP) | VAF 42/126 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.25); catalogued as COSV61733625; called by muse, varscan2
- OR5L2 | c.265G>A p.D89N | Missense Mutation (SNP) | VAF 49/130 reads (38%) | SIFT tolerated (0.25); PolyPhen benign (0.049); catalogued as COSV65723801, COSV65724108; called by muse, mutect2, varscan2
- OR6C74 | c.463T>G p.F155V | Missense Mutation (SNP) | VAF 122/199 reads (61%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.015); catalogued as COSV59605835; called by muse, mutect2, varscan2
- OR7D4 | c.680G>A p.G227E | Missense Mutation (SNP) | VAF 119/193 reads (62%) | SIFT deleterious (0.04); PolyPhen benign (0.027); catalogued as COSV100432616; called by muse, mutect2, varscan2
- OR7G1 | c.79C>T p.P27S | Missense Mutation (SNP) | VAF 17/101 reads (17%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV53317224, COSV99528589; called by muse, mutect2, varscan2
- OR8D2 | c.484C>T p.R162C | Missense Mutation (SNP) | VAF 35/104 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs762105415, COSV62488332; called by muse, mutect2, varscan2
- OR8S1 | c.880G>A p.E294K | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.902); catalogued as COSV59599936, COSV59600401; called by muse, mutect2, varscan2
- OR9A2 | c.293C>T p.S98L | Missense Mutation (SNP) | VAF 46/106 reads (43%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as rs868468706, COSV63306321; called by muse, mutect2, varscan2
- OR9Q2 | c.221C>T p.S74L | Missense Mutation (SNP) | VAF 60/139 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1462827202; called by muse, mutect2, varscan2
- OSBPL10 | c.1700C>T p.S567F | Missense Mutation (SNP) | VAF 49/111 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67336142; called by muse, mutect2, varscan2
- OSBPL5 | c.1349C>T p.P450L | Missense Mutation (SNP) | VAF 97/251 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV55139267; called by muse, mutect2, varscan2
- OTOGL | c.4870G>A p.D1624N (on ENST00000547103; = p.D1615N on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT tolerated (0.93); PolyPhen benign (0.02); catalogued as COSV54013456; called by muse, varscan2
- OTOL1 | c.835C>T p.R279C | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT deleterious (0.05); PolyPhen benign (0.261); catalogued as rs962128557, COSV60006817; called by muse, mutect2, varscan2
- OTOL1 | c.1427C>T p.S476L | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); catalogued as rs748224624, COSV60006772; called by muse, mutect2, varscan2
- P3H2 | c.868G>A p.E290K | Missense Mutation (SNP) | VAF 172/419 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.04); catalogued as rs1483672350, COSV60028635; called by muse, mutect2, varscan2
- PACRG | c.217C>T p.R73* | Nonsense Mutation (SNP) | VAF 58/67 reads (87%) | catalogued as rs376828813, COSV61301828; called by muse, mutect2, varscan2
- PAMR1 | c.1162C>T p.P388S (on ENST00000619888 / NM_001001991.3; = p.P405S on NM_015430.4) | Missense Mutation (SNP) | VAF 47/121 reads (39%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs777895987; called by muse, mutect2, varscan2
- PAPPA | c.2411C>T p.S804F | Missense Mutation (SNP) | VAF 135/157 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs1468111988; called by muse, mutect2, varscan2
3,439 further variants in this file (1,702 protein-altering or splice-affecting, 1,215 silent, 522 other) are not listed here.
